Somatic mutation profile of tumor specimen C3N-02284-01 (aliquot CPT0126670006) from CPTAC case C3N-02284, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 69.9 years (25,536 days).
Specimen C3N-02284-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ead0b60b-213e-4ca2-b06c-3e4b8e93ce71.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02284-31 (Blood Derived Normal), aliquot CPT0126730002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/64c71fc8-1804-4c03-b6f2-78de34e1f4a5

The open-access MAF lists 684 somatic variants for this specimen: 449 protein-altering or splice-affecting, 145 silent, 90 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 376, Silent 145, Intron 36, Nonsense Mutation 34, RNA 19, Frame Shift Del 15, 5'Flank 12, 5'UTR 10, 3'UTR 10, Splice Site 8, Frame Shift Ins 6, Splice Region 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRCA2 | c.8755-1G>C p.X2919_splice | Splice Site (SNP) | VAF 31/121 reads (26%) | catalogued as rs81002812, CS994298; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- COL2A1 | c.1925G>T p.G642V | Missense Mutation (SNP) | VAF 252/472 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as rs1057524602; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.734G>A p.G245D | Missense Mutation (SNP) | VAF 132/465 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121912656, CM010464, CM900209, COSV52666323, COSV52667838, COSV52745465; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.376-1G>A p.X126_splice | Splice Site (SNP) | VAF 88/356 reads (25%) | hotspot (GDC flag); catalogued as rs868137297, CS1313555, COSV52688618, COSV52749979, COSV52994579, COSV52996344; ClinVar: likely pathogenic / pathogenic / not provided; called by muse, mutect2, varscan2
- ADGRB3 | c.3371G>A p.R1124H | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs149298585; called by muse, mutect2, varscan2
- AIRE | c.1622C>T p.A541V | Missense Mutation (SNP) | VAF 243/767 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV52395323; called by muse, mutect2, varscan2
- ALPP | c.41G>A p.G14D | Missense Mutation (SNP) | VAF 110/207 reads (53%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.998); catalogued as rs768223149; called by muse, varscan2
- ANKRD1 | c.640G>A p.A214T | Missense Mutation (SNP) | VAF 123/475 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.037); catalogued as rs758588912, COSV100865301; called by muse, mutect2, varscan2
- ASXL3 | c.988C>A p.P330T | Missense Mutation (SNP) | VAF 39/87 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as COSV52457856, COSV52479162; called by muse, mutect2, varscan2
- ATP8A2 | c.2659G>A p.V887M | Missense Mutation (SNP) | VAF 79/201 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.1); catalogued as rs1191329945; called by muse, mutect2, varscan2
- ATP9A | c.57G>T p.R19S | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as COSV58763346; called by muse, mutect2, varscan2
- ATXN2 | c.944C>T p.S315F (on ENST00000550104; = p.S155F on NM_002973.4) | Missense Mutation (SNP) | VAF 79/196 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as rs746354582; called by muse, mutect2, varscan2
- BPI | c.847C>T p.R283C (on ENST00000262865; = p.R279C on NM_001725.3) | Missense Mutation (SNP) | VAF 75/327 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs775764454, COSV53406552; called by muse, mutect2, varscan2
- BRCA2 | c.8033G>C p.R2678T | Missense Mutation (SNP) | VAF 36/106 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV101204624; called by muse, mutect2, varscan2
- BRCA2 | c.8034G>T p.R2678S | Missense Mutation (SNP) | VAF 36/106 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.692); catalogued as COSV66452199; called by muse, mutect2, varscan2
- C8orf34 | c.242G>T p.R81L | Missense Mutation (SNP) | VAF 86/250 reads (34%) | SIFT tolerated, low confidence (0.18); catalogued as rs956961332; called by muse, mutect2, varscan2
- C8orf37 | c.19G>A p.E7K | Missense Mutation (SNP) | VAF 49/160 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV99713072; called by muse, mutect2, varscan2
- CBLB | c.2651G>T p.R884I | Missense Mutation (SNP) | VAF 46/206 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV51424898, COSV51427825; called by muse, mutect2, varscan2
- CD247 | c.120C>A p.F40L | Missense Mutation (SNP) | VAF 380/811 reads (47%) | SIFT tolerated (0.38); PolyPhen benign (0.218); catalogued as COSV100758386; called by muse, mutect2, varscan2
- CNTN6 | c.2768G>T p.W923L | Missense Mutation (SNP) | VAF 60/127 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63184873; called by muse, mutect2, varscan2
- COL11A2 | c.4066G>T p.A1356S (on ENST00000341947 / NM_080680.3; = p.A1249S on NM_080679.2) | Missense Mutation (SNP) | VAF 219/777 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.039); catalogued as rs764870047; called by muse, mutect2, varscan2
- COL14A1 | c.5021C>G p.P1674R | Missense Mutation (SNP) | VAF 63/253 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.635); catalogued as COSV52853065; called by muse, mutect2, varscan2
- COL22A1 | c.4417G>T p.G1473W | Missense Mutation (SNP) | VAF 83/236 reads (35%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.594); catalogued as COSV57333771, COSV57338092; called by muse, mutect2, varscan2
- COL3A1 | c.118G>A p.A40T | Missense Mutation (SNP) | VAF 113/308 reads (37%) | SIFT tolerated (0.46); PolyPhen benign (0.089); catalogued as rs763720540; called by muse, mutect2, varscan2
- COL6A2 | c.526C>T p.Q176* | Nonsense Mutation (SNP) | VAF 159/228 reads (70%) | catalogued as rs1193526830; called by muse, mutect2, varscan2
- CRYBG2 | c.184G>C p.E62Q | Missense Mutation (SNP) | VAF 47/127 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.617); catalogued as COSV57489583; called by muse, mutect2, varscan2
- CTNNA3 | c.2364G>C p.E788D | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT tolerated (0.85); PolyPhen possibly damaging (0.551); catalogued as COSV65525327; called by muse, mutect2, varscan2
- CUL7 | c.2398-1G>A p.X800_splice | Splice Site (SNP) | VAF 91/254 reads (36%) | catalogued as COSV99538507; called by muse, mutect2, varscan2
- CYP2D6 | c.508C>T p.R170C | Missense Mutation (SNP) | VAF 138/715 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.029); catalogued as rs749131338; called by muse, varscan2
- CYP2D7 | c.508C>T p.R170C | Missense Mutation (SNP) | VAF 28/298 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.031); catalogued as rs760899639; called by muse, mutect2
- DAAM2 | c.2820G>T p.K940N (on ENST00000274867 / NM_001201427.2; = p.K939N on NM_015345.3) | Missense Mutation (SNP) | VAF 43/106 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV99225915; called by muse, mutect2, varscan2
- DGKQ | c.1063C>G p.Q355E | Missense Mutation (SNP) | VAF 183/553 reads (33%) | SIFT tolerated (0.49); PolyPhen benign (0.014); catalogued as rs925577382; called by muse, mutect2, varscan2
- DHX37 | c.3375G>C p.K1125N | Missense Mutation (SNP) | VAF 102/495 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.113); catalogued as COSV58139317; called by muse, mutect2, varscan2
- DNAH5 | c.10717A>G p.I3573V | Missense Mutation (SNP) | VAF 102/395 reads (26%) | SIFT tolerated (0.39); PolyPhen benign (0.173); catalogued as rs1409719852; called by muse, mutect2, varscan2
- DNAJB11 | c.163G>C p.D55H | Missense Mutation (SNP) | VAF 21/265 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54001874; called by muse, mutect2
- DNAJC5G | c.400C>A p.L134I | Missense Mutation (SNP) | VAF 212/384 reads (55%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.835); catalogued as COSV56080733; called by muse, varscan2
- DUOX1 | c.1079C>T p.A360V | Missense Mutation (SNP) | VAF 38/129 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1234733118; called by muse, mutect2, varscan2
- EEF1AKNMT | c.1009G>A p.A337T (on ENST00000361735 / NM_015935.5; = p.A251T on NM_014955.3) | Missense Mutation (SNP) | VAF 97/443 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0.018); catalogued as COSV100675984; called by muse, mutect2, varscan2
- EN1 | c.170C>A p.P57H | Missense Mutation (SNP) | VAF 57/142 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.047); catalogued as rs1234320417; called by muse, mutect2, varscan2
- EPOR | c.1502C>T p.P501L | Missense Mutation (SNP) | VAF 101/323 reads (31%) | SIFT tolerated (0.25); PolyPhen benign (0.027); catalogued as rs1039655747; called by muse, mutect2, varscan2
- EYS | c.3231G>T p.K1077N | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT tolerated (0.05); PolyPhen benign (0.006); catalogued as COSV101011694; called by muse, mutect2, varscan2
- FAP | c.535C>G p.P179A | Missense Mutation (SNP) | VAF 90/132 reads (68%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV51863899; called by muse, mutect2, varscan2
- FAT1 | c.1813C>G p.Q605E | Missense Mutation (SNP) | VAF 64/106 reads (60%) | SIFT tolerated (0.62); PolyPhen benign (0.034); catalogued as COSV71673289; called by muse, mutect2, varscan2
- FLII | c.3128G>A p.G1043D | Missense Mutation (SNP) | VAF 151/533 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1399639101; called by muse, mutect2, varscan2
- FMR1NB | c.340C>A p.Q114K | Missense Mutation (SNP) | VAF 39/62 reads (63%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.654); catalogued as COSV63272765; called by muse, mutect2, varscan2
- FRMPD4 | c.2752G>C p.E918Q | Missense Mutation (SNP) | VAF 94/121 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66217812; called by muse, mutect2, varscan2
- GABRB3 | c.621G>T p.E207D | Missense Mutation (SNP) | VAF 253/745 reads (34%) | SIFT tolerated (0.19); PolyPhen benign (0.192); catalogued as COSV54686967; called by muse, mutect2, varscan2
- GALNTL5 | c.133G>C p.A45P | Missense Mutation (SNP) | VAF 155/430 reads (36%) | SIFT tolerated (0.28); PolyPhen benign (0.086); catalogued as rs1352113272, COSV67180208; called by muse, mutect2, varscan2
- GDF6 | c.379A>G p.I127V | Missense Mutation (SNP) | VAF 110/382 reads (29%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.557); catalogued as rs1324983536; called by muse, mutect2, varscan2
- GFRAL | c.416T>C p.V139A | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.699); catalogued as COSV100475322; called by muse, mutect2, varscan2
- GIT2 | c.2263A>G p.K755E (on ENST00000355312 / NM_057169.5; = p.K677E on NM_014776.5) | Missense Mutation (SNP) | VAF 92/298 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.437); catalogued as rs1247152700; called by muse, mutect2, varscan2
- GON7 | c.71C>A p.P24Q | Missense Mutation (SNP) | VAF 165/442 reads (37%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.912); catalogued as COSV50148862; called by muse, mutect2, varscan2
- GPC2 | c.539C>T p.P180L | Missense Mutation (SNP) | VAF 155/511 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1345171872; called by muse, mutect2, varscan2
- GRAMD1C | c.1141A>T p.T381S | Missense Mutation (SNP) | VAF 76/134 reads (57%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.985); catalogued as COSV63983845; called by muse, varscan2
- HBZ | c.37T>C p.S13P | Missense Mutation (SNP) | VAF 141/397 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.634); catalogued as rs142309434; called by muse, mutect2
- ICA1 | c.946A>G p.S316G | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs1338529928; called by muse, mutect2, varscan2
- IRX2 | c.1265A>G p.H422R | Missense Mutation (SNP) | VAF 128/589 reads (22%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.049); catalogued as rs1327178653; called by muse, mutect2, varscan2
- JUNB | c.89A>G p.H30R | Missense Mutation (SNP) | VAF 97/286 reads (34%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as COSV56878168; called by muse, mutect2, varscan2
- KIR3DL2 | c.562G>T p.V188F | Missense Mutation (SNP) | VAF 592/855 reads (69%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.519); catalogued as COSV99551695; called by muse, mutect2, varscan2
- KNG1 | c.1264G>C p.E422Q | Missense Mutation (SNP) | VAF 85/238 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.896); catalogued as COSV53976096; called by muse, mutect2, varscan2
- KSR1 | c.1233C>G p.I411M (on ENST00000644974 / NM_001367810.1; = p.I274M on NM_014238.2) | Missense Mutation (SNP) | VAF 42/149 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52030222; called by muse, mutect2, varscan2
- LAMC1 | c.2848C>T p.R950C | Missense Mutation (SNP) | VAF 104/539 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.424); catalogued as rs757720218, COSV51137550; called by muse, mutect2, varscan2
- LILRB3 | c.1876C>A p.Q626K (on ENST00000346401; = p.Q614K on NM_006864.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 153/474 reads (32%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.734); catalogued as COSV54446475; called by muse, mutect2, varscan2
- LRIT1 | c.102G>C p.M34I | Missense Mutation (SNP) | VAF 128/366 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV63894801; called by muse, mutect2, varscan2
- LRRC71 | c.1268G>A p.S423N | Missense Mutation (SNP) | VAF 200/447 reads (45%) | SIFT tolerated (0.33); PolyPhen benign (0.081); catalogued as rs369222584; called by muse, mutect2, varscan2
- MAB21L1 | c.671C>A p.S224* | Nonsense Mutation (SNP) | VAF 77/409 reads (19%) | catalogued as COSV100077792, COSV59795245; called by muse, mutect2, varscan2
- MAGEB6B | c.982G>A p.A328T | Missense Mutation (SNP) | VAF 80/147 reads (54%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as rs1569250381; called by muse, mutect2, varscan2
- MAP3K13 | c.1765C>T p.R589C | Missense Mutation (SNP) | VAF 161/744 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs765513332; called by muse, mutect2, varscan2
- MLH3 | c.2021dup p.N674Kfs*13 | Frame Shift Ins (INS) | VAF 36/126 reads (29%) | catalogued as rs767782578; ClinVar: uncertain significance; called by mutect2, varscan2
- MRC2 | c.3562G>T p.A1188S | Missense Mutation (SNP) | VAF 35/93 reads (38%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as rs1292475142; called by muse, mutect2, varscan2
- MRGPRX4 | c.368C>A p.S123Y | Missense Mutation (SNP) | VAF 78/130 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58590680; called by muse, mutect2, varscan2
- MUC16 | c.6710T>C p.I2237T | Missense Mutation (SNP) | VAF 54/149 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.039); catalogued as rs532869358, COSV67492287; called by muse, mutect2, varscan2
- MYH15 | c.4599G>C p.K1533N | Missense Mutation (SNP) | VAF 35/106 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV99843126; called by muse, mutect2, varscan2
- MYO7B | c.3298G>A p.A1100T | Missense Mutation (SNP) | VAF 169/245 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs534630323; called by muse, mutect2, varscan2
- NBEA | c.1069G>T p.A357S | Missense Mutation (SNP) | VAF 72/124 reads (58%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.992); catalogued as COSV100082840; called by muse, mutect2, varscan2
- NCSTN | c.1969C>G p.R657G | Missense Mutation (SNP) | VAF 203/705 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as COSV99667189; called by muse, mutect2, varscan2
- NDUFB4 | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 238/726 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.116); catalogued as COSV51742311; called by muse, mutect2, varscan2
- NDUFV1 | c.818C>T p.T273I | Missense Mutation (SNP) | VAF 141/648 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.939); catalogued as rs1237891453; called by muse, mutect2, varscan2
- NECTIN4 | c.1400G>T p.R467L | Missense Mutation (SNP) | VAF 230/820 reads (28%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.694); catalogued as COSV63513341; called by muse, mutect2, varscan2
- NEFL | c.1155G>T p.E385D | Missense Mutation (SNP) | VAF 85/160 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV55336203; called by muse, mutect2, varscan2
- NES | c.3223G>A p.G1075S | Missense Mutation (SNP) | VAF 57/168 reads (34%) | SIFT tolerated (0.32); PolyPhen benign (0.006); catalogued as COSV63961126; called by muse, mutect2, varscan2
- NOTCH1 | c.1315C>T p.Q439* | Nonsense Mutation (SNP) | VAF 167/283 reads (59%) | catalogued as COSV53053276; called by muse, mutect2, varscan2
- NT5C | c.248C>A p.A83D | Missense Mutation (SNP) | VAF 109/325 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766310077; called by muse, mutect2, varscan2
- OBSCN | c.21538G>T p.G7180C | Missense Mutation (SNP) | VAF 109/228 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs773768615; called by muse, mutect2, varscan2
- OPRPN | c.535A>G p.T179A | Missense Mutation (SNP) | VAF 46/100 reads (46%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.074); catalogued as rs1332213281; called by muse, mutect2, varscan2
- OR10C1 | c.704G>A p.R235H (on ENST00000622521; = p.R233H on NM_013941.3) | Missense Mutation (SNP) | VAF 119/335 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.099); catalogued as rs771138562, COSV101010813, COSV65822160; called by muse, mutect2, varscan2
- OR4A5 | c.703T>A p.S235T | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.876); catalogued as COSV99081993; called by muse, mutect2, varscan2
- OR6K6 | c.789G>T p.K263N (on ENST00000368144; = p.K239N on NM_001005184.1) | Missense Mutation (SNP) | VAF 147/269 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs959595032; called by muse, mutect2, varscan2
- OTC | c.378C>A p.D126E | Missense Mutation (SNP) | VAF 85/144 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1182076950, COSV50000564; called by muse, mutect2, varscan2
- OTOL1 | c.1223A>T p.Q408L | Missense Mutation (SNP) | VAF 67/314 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.062); catalogued as COSV60006999; called by muse, mutect2, varscan2
- OXCT2 | c.1088C>T p.A363V | Missense Mutation (SNP) | VAF 58/314 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.95); catalogued as rs1433678369; called by muse, mutect2, varscan2
- PCDH17 | c.1399G>A p.D467N | Missense Mutation (SNP) | VAF 146/285 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV64974223; called by muse, mutect2, varscan2
- PCDH19 | c.2012C>A p.S671* | Nonsense Mutation (SNP) | VAF 261/373 reads (70%) | catalogued as CM081733; called by muse, mutect2, varscan2
- PCDHB10 | c.574C>A p.P192T | Missense Mutation (SNP) | VAF 97/186 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV53384168; called by muse, mutect2, varscan2
- PLXND1 | c.1718C>T p.T573M | Missense Mutation (SNP) | VAF 54/221 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as rs151013320; called by muse, mutect2, varscan2
- POLR3B | c.2333C>T p.T778M | Missense Mutation (SNP) | VAF 239/482 reads (50%) | SIFT tolerated (0.18); PolyPhen benign (0.041); catalogued as rs375480706; called by muse, mutect2, varscan2
- POPDC2 | c.386T>C p.I129T | Missense Mutation (SNP) | VAF 39/148 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs749422208; called by muse, mutect2, varscan2
- PRSS1 | c.547A>G p.M183V | Missense Mutation (SNP) | VAF 144/457 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as rs200070487; called by muse, mutect2, varscan2
- PSMD9 | c.424A>G p.I142V | Missense Mutation (SNP) | VAF 222/497 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1454402054; called by muse, mutect2, varscan2
- PTPRC | c.209C>T p.S70L | Missense Mutation (SNP) | VAF 122/526 reads (23%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.007); catalogued as COSV61420318; called by muse, mutect2, varscan2
- PTPRR | c.387C>G p.N129K | Missense Mutation (SNP) | VAF 97/362 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.411); catalogued as COSV51739033; called by muse, mutect2, varscan2
- PTPRT | c.3806G>C p.C1269S | Missense Mutation (SNP) | VAF 100/273 reads (37%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.909); catalogued as COSV62037588; called by muse, mutect2, varscan2
- RILPL1 | c.533G>T p.R178L | Missense Mutation (SNP) | VAF 195/445 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61552934; called by muse, mutect2, varscan2
- RIMBP2 | c.319G>A p.A107T | Missense Mutation (SNP) | VAF 51/173 reads (29%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs745629723; called by muse, mutect2, varscan2
- RIMS1 | c.4588G>A p.G1530S | Missense Mutation (SNP) | VAF 213/662 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99328056; called by muse, mutect2, varscan2
- ROBO2 | c.2050T>A p.W684R | Missense Mutation (SNP) | VAF 73/133 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100165380; called by muse, mutect2, varscan2
- RPS25 | c.7C>T p.P3S | Missense Mutation (SNP) | VAF 93/264 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as rs782672502; called by muse, mutect2, varscan2
- SAMD9L | c.118G>T p.E40* | Nonsense Mutation (SNP) | VAF 34/132 reads (26%) | catalogued as COSV59079590; called by muse, mutect2, varscan2
- SBK3 | c.916G>A p.D306N | Missense Mutation (SNP) | VAF 57/178 reads (32%) | SIFT tolerated (0.48); PolyPhen benign (0.08); catalogued as rs1399861045; called by muse, mutect2, varscan2
- SDC3 | c.1178G>A p.G393E | Missense Mutation (SNP) | VAF 37/139 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV59579832; called by muse, mutect2, varscan2
- SHQ1 | c.1303G>T p.A435S | Missense Mutation (SNP) | VAF 82/185 reads (44%) | SIFT tolerated (0.33); PolyPhen benign (0.005); catalogued as COSV57768415; called by muse, mutect2, varscan2
- SLC12A3 | c.2228A>G p.K743R | Missense Mutation (SNP) | VAF 105/363 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs778660543; called by muse, mutect2, varscan2
- SLC5A2 | c.14C>G p.T5R | Missense Mutation (SNP) | VAF 112/346 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs748202554; called by muse, mutect2, varscan2
- SNX20 | c.406G>A p.E136K | Missense Mutation (SNP) | VAF 84/297 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs750713594, COSV56058092; called by muse, mutect2, varscan2
- SNX20 | c.405C>G p.I135M | Missense Mutation (SNP) | VAF 83/293 reads (28%) | SIFT tolerated (0.83); PolyPhen benign (0.041); catalogued as COSV56058099; called by muse, mutect2, varscan2
- SORCS2 | c.946G>T p.G316C | Missense Mutation (SNP) | VAF 111/342 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.661); catalogued as COSV100211919; called by muse, mutect2, varscan2
- SPAG17 | c.1945C>A p.Q649K | Missense Mutation (SNP) | VAF 65/131 reads (50%) | SIFT tolerated (0.98); PolyPhen benign (0.007); catalogued as COSV100309903; called by muse, mutect2, varscan2
- SPEN | c.7024C>T p.R2342* | Nonsense Mutation (SNP) | VAF 90/253 reads (36%) | catalogued as COSV65362645; called by muse, mutect2, varscan2
- SPTA1 | c.2053G>T p.E685* | Nonsense Mutation (SNP) | VAF 131/541 reads (24%) | catalogued as COSV100935751; called by muse, mutect2, varscan2
- SPTA1 | c.575G>T p.R192L | Missense Mutation (SNP) | VAF 145/598 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.624); catalogued as COSV100935831, COSV63757423; called by muse, mutect2, varscan2
- SUPT3H | c.344G>T p.R115L (on ENST00000371460 / NM_181356.3; = p.R104L on NM_003599.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/106 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV100178432; called by muse, mutect2, varscan2
- TBX5 | c.1542G>C p.W514C | Missense Mutation (SNP) | VAF 194/430 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100091313; called by muse, varscan2
- TENM3 | c.7880G>T p.R2627L | Missense Mutation (SNP) | VAF 49/77 reads (64%) | SIFT deleterious (0); PolyPhen benign (0.139); catalogued as COSV69302576; called by muse, mutect2, varscan2
- TEX45 | c.1343C>G p.S448* | Nonsense Mutation (SNP) | VAF 94/310 reads (30%) | catalogued as rs757485099; called by muse, mutect2, varscan2
- TG | c.2483G>T p.G828V | Missense Mutation (SNP) | VAF 158/955 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55095458; called by muse, varscan2
- TG | c.6129G>T p.W2043C | Missense Mutation (SNP) | VAF 132/751 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55085285; called by muse, varscan2
- TNIK | c.239G>A p.R80Q | Missense Mutation (SNP) | VAF 37/194 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as rs755888335, COSV99454884; called by muse, mutect2, varscan2
- TPO | c.1558C>A p.H520N | Missense Mutation (SNP) | VAF 134/350 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.22); catalogued as COSV61110083; called by muse, mutect2, varscan2
- TRAV1-2 | c.244A>T p.S82C | Missense Mutation (SNP) | VAF 70/191 reads (37%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.78); catalogued as rs759763628; called by muse, mutect2, varscan2
- TRIM51 | c.2T>A p.M1? | Translation Start Site (SNP) | VAF 47/191 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV55269358; called by muse, mutect2, varscan2
- TRIM51 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 49/194 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.468); catalogued as COSV55265539, COSV55266654; called by muse, mutect2, varscan2
- TRIO | c.2245C>T p.P749S | Missense Mutation (SNP) | VAF 160/282 reads (57%) | SIFT tolerated (0.07); PolyPhen benign (0.026); catalogued as rs1443527118; called by muse, mutect2, varscan2
- TTLL6 | c.2617G>C p.D873H (on ENST00000393382 / NM_001130918.3; = p.D566H on NM_173623.3) | Missense Mutation (SNP) | VAF 78/219 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.843); catalogued as COSV64978489; called by muse, mutect2, varscan2
- TTN | c.7482T>G p.I2494M (on ENST00000591111; = p.I2448M on NM_003319.4) | Missense Mutation (SNP) | VAF 90/299 reads (30%) | PolyPhen possibly damaging (0.748); catalogued as rs749215640, COSV100620453; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- VEPH1 | c.1888G>C p.E630Q | Missense Mutation (SNP) | VAF 78/263 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.031); catalogued as rs1220977108; called by muse, mutect2, varscan2
- VPS13C | c.278G>T p.G93V | Missense Mutation (SNP) | VAF 54/144 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.884); catalogued as rs759149177; called by muse, mutect2, varscan2
- VPS33A | c.1396A>G p.I466V | Missense Mutation (SNP) | VAF 48/211 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.065); catalogued as rs556251997; called by muse, mutect2, varscan2
- WASF3 | c.920del p.P307Rfs*28 | Frame Shift Del (DEL) | VAF 38/142 reads (27%) | catalogued as rs756173793; called by mutect2, varscan2
- ZFHX4 | c.7995C>A p.F2665L | Missense Mutation (SNP) | VAF 82/133 reads (62%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.784); catalogued as COSV50803129; called by muse, mutect2, varscan2
- ZFP42 | c.809C>A p.T270K | Missense Mutation (SNP) | VAF 107/214 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58817829; called by muse, mutect2, varscan2
- ZNF230 | c.795C>G p.F265L | Missense Mutation (SNP) | VAF 48/91 reads (53%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV71273400; called by muse, mutect2, varscan2
- ZNF729 | c.2209G>C p.E737Q | Missense Mutation (SNP) | VAF 78/232 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.579); catalogued as COSV62606258; called by muse, varscan2
- ZSCAN1 | c.655G>T p.D219Y | Missense Mutation (SNP) | VAF 66/190 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.211); catalogued as COSV56607461; called by muse, varscan2
- ABCA8 | c.627G>T p.M209I | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.58); called by muse, mutect2, varscan2
- ABCA9 | c.2265G>C p.R755S | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ABI3BP | c.1477C>A p.P493T | Missense Mutation (SNP) | VAF 54/211 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- ACACA | c.4231G>T p.E1411* | Nonsense Mutation (SNP) | VAF 123/326 reads (38%) | called by muse, mutect2, varscan2
- ACACB | c.3125T>G p.L1042R | Missense Mutation (SNP) | VAF 184/446 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ACADSB | c.691G>T p.G231* | Nonsense Mutation (SNP) | VAF 86/283 reads (30%) | called by muse, mutect2, varscan2
- ACOT11 | c.1819_1820del p.T607Lfs*73 | Frame Shift Del (DEL) | VAF 48/223 reads (22%) | called by pindel, varscan2
- ADAM12 | c.1270G>T p.G424C | Missense Mutation (SNP) | VAF 130/335 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ADAM22 | c.2657C>A p.P886Q (on ENST00000265727 / NM_001324420.2; = p.P850Q on NM_016351.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 58/223 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADAMTS12 | c.2722G>A p.V908M | Missense Mutation (SNP) | VAF 85/329 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- ADAMTS16 | c.1590G>C p.M530I | Missense Mutation (SNP) | VAF 53/144 reads (37%) | SIFT tolerated (0.25); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- ADAMTS7 | c.2461C>A p.P821T | Missense Mutation (SNP) | VAF 227/398 reads (57%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.521); called by muse, mutect2, varscan2
- ADCK1 | c.1182C>G p.S394R | Missense Mutation (SNP) | VAF 124/332 reads (37%) | SIFT tolerated (0.29); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ADCY2 | c.2942T>A p.V981E | Missense Mutation (SNP) | VAF 85/280 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- ADCY8 | c.2633C>A p.A878E | Missense Mutation (SNP) | VAF 107/223 reads (48%) | SIFT tolerated (0.53); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- ADGRG4 | c.659C>A p.P220Q | Missense Mutation (SNP) | VAF 21/35 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AHCYL2 | c.928G>A p.D310N | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.551); called by muse, mutect2, varscan2
- AKAP6 | c.35G>T p.R12M | Missense Mutation (SNP) | VAF 60/140 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.116); called by muse, varscan2
- AKTIP | c.555C>G p.F185L | Missense Mutation (SNP) | VAF 47/146 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- ALAS2 | c.257A>G p.Q86R | Missense Mutation (SNP) | VAF 138/187 reads (74%) | SIFT tolerated (0.62); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ALG1L | c.461C>T p.P154L | Missense Mutation (SNP) | VAF 460/644 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ALOX5 | c.220A>T p.K74* | Nonsense Mutation (SNP) | VAF 168/583 reads (29%) | called by muse, mutect2, varscan2
- ANKRD34A | c.518C>G p.P173R | Missense Mutation (SNP) | VAF 73/252 reads (29%) | SIFT tolerated (0.39); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ANTXRL | c.563C>G p.A188G | Missense Mutation (SNP) | VAF 80/268 reads (30%) | SIFT tolerated (0.37); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- AP4S1 | c.275A>G p.D92G | Missense Mutation (SNP) | VAF 93/286 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ARID5B | c.2041A>T p.R681W | Missense Mutation (SNP) | VAF 40/112 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- ARX | c.137C>T p.A46V | Missense Mutation (SNP) | VAF 293/401 reads (73%) | SIFT tolerated (0.09); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- ASIC3 | c.1346G>A p.S449N | Missense Mutation (SNP) | VAF 140/497 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); called by muse, mutect2, varscan2
- ATRNL1 | c.3180T>G p.C1060W | Missense Mutation (SNP) | VAF 6/140 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- BAAT | c.907C>A p.Q303K | Missense Mutation (SNP) | VAF 173/334 reads (52%) | SIFT tolerated (0.87); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- BEND3 | c.793del p.D265Tfs*54 | Frame Shift Del (DEL) | VAF 88/280 reads (31%) | called by mutect2, varscan2
- BIN1 | c.1390G>A p.V464M (on ENST00000316724 / NM_001320642.1; = p.V325M on NM_004305.4) | Missense Mutation (SNP) | VAF 206/617 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.435); called by muse, mutect2, varscan2
- BIRC6 | c.11599T>C p.S3867P | Missense Mutation (SNP) | VAF 76/264 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.283); called by muse, mutect2, varscan2
- C6 | c.1766G>A p.C589Y | Missense Mutation (SNP) | VAF 103/409 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- C6 | c.1344G>T p.R448S | Missense Mutation (SNP) | VAF 50/196 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); called by muse, mutect2, varscan2
- CACTIN | c.1279G>T p.A427S | Missense Mutation (SNP) | VAF 203/710 reads (29%) | SIFT tolerated (0.63); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- CAPN11 | c.2062T>A p.Y688N | Missense Mutation (SNP) | VAF 95/311 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- CASQ2 | c.606G>A p.G202= | Splice Region (SNP) | VAF 52/108 reads (48%) | called by muse, mutect2, varscan2
- CBLB | c.2652A>T p.R884S | Missense Mutation (SNP) | VAF 44/202 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- CCDC150 | c.2217G>T p.W739C | Missense Mutation (SNP) | VAF 121/374 reads (32%) | SIFT tolerated (0.39); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- CCDC166 | c.83C>A p.S28* | Nonsense Mutation (SNP) | VAF 61/286 reads (21%) | called by muse, mutect2, varscan2
- CCDC170 | c.1127T>C p.L376P | Missense Mutation (SNP) | VAF 87/298 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- CCDC30 | c.1428G>T p.M476I (on ENST00000340612; = p.M433I on NM_001080850.3) | Missense Mutation (SNP) | VAF 60/169 reads (36%) | SIFT tolerated (0.38); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- CDH18 | c.2229G>T p.Q743H | Missense Mutation (SNP) | VAF 110/522 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- CDH2 | c.1099A>C p.T367P | Missense Mutation (SNP) | VAF 35/218 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- CDK17 | c.818A>G p.D273G | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CENPC | c.1018C>G p.L340V | Missense Mutation (SNP) | VAF 8/238 reads (3%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- CEP162 | c.1099C>A p.Q367K | Missense Mutation (SNP) | VAF 54/165 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.225); called by muse, mutect2, varscan2
- CHD8 | c.4703A>G p.K1568R (on ENST00000646647 / NM_001170629.2; = p.K1289R on NM_020920.4) | Missense Mutation (SNP) | VAF 59/157 reads (38%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.463); called by muse, mutect2, varscan2
- CHL1 | c.3366C>A p.D1122E (on ENST00000397491 / NM_001253387.1; = p.D1138E on NM_006614.4) | Missense Mutation (SNP) | VAF 21/34 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- CHRM3 | c.1689T>A p.C563* | Nonsense Mutation (SNP) | VAF 87/160 reads (54%) | called by muse, mutect2, varscan2
- CLCNKA | c.865G>T p.G289C | Missense Mutation (SNP) | VAF 158/700 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- CLN6 | c.828G>T p.W276C | Missense Mutation (SNP) | VAF 244/1397 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CMPK2 | c.748G>T p.G250* | Nonsense Mutation (SNP) | VAF 78/234 reads (33%) | called by muse, mutect2, varscan2
- CNTN6 | c.2769G>T p.W923C | Missense Mutation (SNP) | VAF 62/128 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CNTNAP3 | c.15_17del p.W6del | In Frame Del (DEL) | VAF 22/127 reads (17%) | called by mutect2, pindel, varscan2
- COL1A2 | c.2449G>T p.G817W | Missense Mutation (SNP) | VAF 174/532 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL20A1 | c.3236C>A p.P1079H | Missense Mutation (SNP) | VAF 131/229 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- COL2A1 | c.2257G>A p.G753S | Missense Mutation (SNP) | VAF 235/556 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COLGALT1 | c.1676C>T p.T559I | Missense Mutation (SNP) | VAF 138/414 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COQ3 | c.844G>T p.E282* | Nonsense Mutation (SNP) | VAF 47/121 reads (39%) | called by muse, mutect2, varscan2
- CPPED1 | c.165C>G p.D55E | Missense Mutation (SNP) | VAF 187/511 reads (37%) | SIFT tolerated (0.16); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- CPSF4 | c.100G>A p.D34N | Missense Mutation (SNP) | VAF 88/254 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- CPSF7 | c.364G>T p.G122C (on ENST00000394888 / NM_001136040.4; = p.G165C on NM_024811.4) | Missense Mutation (SNP) | VAF 66/174 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- CRYBG1 | c.4994A>C p.H1665P | Missense Mutation (SNP) | VAF 52/168 reads (31%) | SIFT tolerated (0.28); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CSMD1 | c.1679dup p.V561Gfs*68 (on ENST00000520002; = p.V560Gfs*68 on NM_033225.6) | Frame Shift Ins (INS) | VAF 79/194 reads (41%) | called by mutect2, pindel, varscan2
- CSMD3 | c.5988T>A p.Y1996* (on ENST00000297405 / NM_001363185.1; = p.Y1892* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 183/285 reads (64%) | called by muse, mutect2, varscan2
- CUBN | c.10625T>C p.V3542A | Missense Mutation (SNP) | VAF 153/415 reads (37%) | SIFT tolerated (0.75); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- CYP11B2 | c.1484C>A p.P495H | Missense Mutation (SNP) | VAF 180/469 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- DCAF4L2 | c.725G>T p.G242V | Missense Mutation (SNP) | VAF 183/312 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DCAF4L2 | c.724G>A p.G242S | Missense Mutation (SNP) | VAF 183/310 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DDHD1 | c.1615G>T p.G539* (on ENST00000323669; = p.G736* on NM_030637.3) | Nonsense Mutation (SNP) | VAF 69/224 reads (31%) | called by muse, mutect2, varscan2
- DDX53 | c.289G>T p.G97C | Missense Mutation (SNP) | VAF 22/38 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DENND1B | c.1734_1735del p.H578Qfs*17 | Frame Shift Del (DEL) | VAF 50/170 reads (29%) | called by pindel, varscan2
- DGKI | c.3182dup p.E1062Gfs*48 | Frame Shift Ins (INS) | VAF 93/329 reads (28%) | called by mutect2, pindel, varscan2
- DGKI | c.1665dup p.S556Qfs*6 | Frame Shift Ins (INS) | VAF 29/125 reads (23%) | called by mutect2, pindel, varscan2
- DISP2 | c.2888A>T p.E963V | Missense Mutation (SNP) | VAF 113/298 reads (38%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DMXL1 | c.8501G>T p.W2834L | Missense Mutation (SNP) | VAF 55/102 reads (54%) | SIFT tolerated (0.42); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DNAH5 | c.2419T>A p.F807I | Missense Mutation (SNP) | VAF 38/191 reads (20%) | SIFT tolerated (0.43); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- DNAH6 | c.5701G>T p.E1901* | Nonsense Mutation (SNP) | VAF 63/243 reads (26%) | called by muse, mutect2, varscan2
- DNAH9 | c.8883G>T p.K2961N | Missense Mutation (SNP) | VAF 84/234 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- DPP9 | c.892A>T p.R298W (on ENST00000598800; = p.R327W on NM_139159.5) | Missense Mutation (SNP) | VAF 65/179 reads (36%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- DSG2 | c.1420G>T p.E474* | Nonsense Mutation (SNP) | VAF 44/129 reads (34%) | called by muse, mutect2, varscan2
- DVL1 | c.1063G>A p.V355M | Missense Mutation (SNP) | VAF 89/264 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- DYNLRB2 | c.81T>A p.G27= | Splice Region (SNP) | VAF 10/38 reads (26%) | called by muse, mutect2, varscan2
- EGR4 | c.1139G>A p.G380E (on ENST00000545030; = p.G277E on NM_001965.4) | Missense Mutation (SNP) | VAF 46/146 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- EMX2 | c.200C>A p.P67Q | Missense Mutation (SNP) | VAF 119/323 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- EN2 | c.139G>A p.A47T | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.026); called by muse, mutect2
- EPHA4 | c.2911G>T p.A971S | Missense Mutation (SNP) | VAF 119/262 reads (45%) | SIFT tolerated (0.66); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- EPHB1 | c.2609G>T p.R870L | Missense Mutation (SNP) | VAF 111/174 reads (64%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- ETS1 | c.171G>T p.M57I | Missense Mutation (SNP) | VAF 35/108 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- EXD3 | c.28C>T p.P10S | Missense Mutation (SNP) | VAF 144/278 reads (52%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- F13B | c.573G>T p.K191N | Missense Mutation (SNP) | VAF 183/345 reads (53%) | SIFT tolerated (0.33); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- FAM189A1 | c.1054G>T p.G352C | Missense Mutation (SNP) | VAF 68/232 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.635); called by muse, mutect2, varscan2
- FAM228B | c.821G>T p.R274I | Missense Mutation (SNP) | VAF 46/180 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- FAM43B | c.89C>T p.T30M | Missense Mutation (SNP) | VAF 246/667 reads (37%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.476); called by muse, mutect2, varscan2
- FGFR1 | c.470C>A p.S157Y (on ENST00000447712 / NM_023110.3; = p.S155Y on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 81/216 reads (38%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, mutect2, varscan2
- FLG | c.4414C>A p.Q1472K | Missense Mutation (SNP) | VAF 130/651 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.175); called by muse, mutect2, varscan2
- FOXN3 | c.146T>C p.L49S | Missense Mutation (SNP) | VAF 86/246 reads (35%) | called by muse, mutect2, varscan2
- FOXP2 | c.1922T>G p.V641G | Missense Mutation (SNP) | VAF 112/341 reads (33%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- FREM3 | c.2535T>A p.F845L | Missense Mutation (SNP) | VAF 108/204 reads (53%) | SIFT tolerated (0.13); PolyPhen benign (0.238); called by muse, mutect2, varscan2
- FSBP | c.403G>A p.G135S | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.585); called by muse, mutect2, varscan2
- FTCD | c.969-2A>C p.X323_splice | Splice Site (SNP) | VAF 159/215 reads (74%) | called by muse, mutect2, varscan2
- GABRB2 | c.459-1G>C p.X153_splice | Splice Site (SNP) | VAF 54/98 reads (55%) | called by muse, mutect2, varscan2
- GALNTL5 | c.728C>T p.A243V | Missense Mutation (SNP) | VAF 136/427 reads (32%) | SIFT tolerated (0.36); PolyPhen benign (0.231); called by muse, mutect2, varscan2
- GAS1 | c.446G>T p.R149L | Missense Mutation (SNP) | VAF 83/150 reads (55%) | SIFT deleterious (0.03); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- GLI1 | c.2419G>T p.E807* | Nonsense Mutation (SNP) | VAF 62/129 reads (48%) | called by muse, mutect2, varscan2
- GLI4 | c.296C>T p.A99V | Missense Mutation (SNP) | VAF 67/261 reads (26%) | SIFT tolerated (0.57); PolyPhen benign (0); called by muse, mutect2, varscan2
- GMEB1 | c.910C>G p.L304V | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- GNS | c.536C>G p.S179C | Missense Mutation (SNP) | VAF 160/311 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GOLGA6L9 | c.449C>T p.P150L | Missense Mutation (SNP) | VAF 282/499 reads (57%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- GOLGA8K | c.223C>G p.L75V | Missense Mutation (SNP) | VAF 43/116 reads (37%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.466); called by mutect2, varscan2
- GON4L | c.1676A>G p.Y559C | Missense Mutation (SNP) | VAF 139/546 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- GPR158 | c.1430G>A p.S477N | Missense Mutation (SNP) | VAF 73/203 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GRAMD1C | c.1202A>G p.E401G | Missense Mutation (SNP) | VAF 60/94 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, varscan2
- GRIA1 | c.242G>C p.G81A | Missense Mutation (SNP) | VAF 95/162 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- GRIK2 | c.1593G>T p.K531N | Missense Mutation (SNP) | VAF 84/242 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GRIN2B | c.3743C>A p.A1248E | Missense Mutation (SNP) | VAF 192/278 reads (69%) | SIFT tolerated (0.08); PolyPhen benign (0.324); called by muse, mutect2, varscan2
- GRIPAP1 | c.407A>G p.E136G | Missense Mutation (SNP) | VAF 25/40 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- H2BC10 | c.144G>C p.Q48H | Missense Mutation (SNP) | VAF 136/512 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- H3C11 | c.94G>A p.A32T | Missense Mutation (SNP) | VAF 79/234 reads (34%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- HDHD5 | c.571+7G>C | Splice Region (SNP) | VAF 64/199 reads (32%) | called by muse, mutect2, varscan2
- HECW2 | c.1919G>A p.C640Y | Missense Mutation (SNP) | VAF 40/91 reads (44%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- HIBADH | c.601G>T p.A201S | Missense Mutation (SNP) | VAF 86/244 reads (35%) | SIFT tolerated (0.72); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- HRC | c.126C>A p.N42K | Missense Mutation (SNP) | VAF 283/424 reads (67%) | SIFT deleterious (0); PolyPhen benign (0.19); called by muse, mutect2, varscan2
- HYDIN | c.358C>A p.L120M | Missense Mutation (SNP) | VAF 33/104 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IFNL2 | c.226C>T p.H76Y | Missense Mutation (SNP) | VAF 86/179 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- IGKV2D-24 | c.177T>A p.S59R | Missense Mutation (SNP) | VAF 131/204 reads (64%) | SIFT tolerated (0.18); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- IGLV7-43 | c.215C>G p.T72R | Missense Mutation (SNP) | VAF 22/502 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); called by muse, mutect2
- IL17C | c.409G>T p.A137S | Missense Mutation (SNP) | VAF 115/375 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- IL27 | c.245C>T p.P82L | Missense Mutation (SNP) | VAF 61/216 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- IPO7 | c.635A>T p.Q212L | Missense Mutation (SNP) | VAF 43/67 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- IRAK3 | c.499A>G p.K167E | Missense Mutation (SNP) | VAF 49/135 reads (36%) | SIFT tolerated (0.91); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- ITGAD | c.1417G>T p.D473Y | Missense Mutation (SNP) | VAF 83/262 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ITGAM | c.1711C>G p.R571G (on ENST00000648685 / NM_001145808.2; = p.R570G on NM_000632.4) | Missense Mutation (SNP) | VAF 52/149 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- JAKMIP1 | c.1411C>T p.P471S | Missense Mutation (SNP) | VAF 113/349 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KCNF1 | c.1336C>A p.R446S | Missense Mutation (SNP) | VAF 56/126 reads (44%) | SIFT tolerated (0.38); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- KCNH5 | c.2773A>T p.S925C | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.682); called by muse, mutect2
- KCNK15 | c.176A>G p.Y59C | Missense Mutation (SNP) | VAF 39/133 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- KCNQ5 | c.2542G>A p.G848R | Missense Mutation (SNP) | VAF 127/329 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- KCTD12 | c.782G>T p.R261L | Missense Mutation (SNP) | VAF 186/382 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KDM2A | c.2180A>G p.H727R | Missense Mutation (SNP) | VAF 70/309 reads (23%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- KIAA0319 | c.2353del p.V785Cfs*36 | Frame Shift Del (DEL) | VAF 104/395 reads (26%) | called by mutect2, pindel, varscan2
- KIAA1210 | c.4022A>T p.K1341I | Missense Mutation (SNP) | VAF 107/159 reads (67%) | SIFT deleterious (0.01); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- KIAA2012 | c.2146G>A p.D716N | Missense Mutation (SNP) | VAF 59/196 reads (30%) | SIFT tolerated (0.08); called by muse, mutect2, varscan2
- KIF23 | c.2648C>G p.T883R (on ENST00000260363; = p.T779R on NM_004856.7) | Missense Mutation (SNP) | VAF 42/216 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- KLC4 | c.292G>C p.V98L | Missense Mutation (SNP) | VAF 156/477 reads (33%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.532); called by muse, mutect2, varscan2
- KLHL1 | c.326G>T p.G109V | Missense Mutation (SNP) | VAF 135/266 reads (51%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- KLHL1 | c.325G>A p.G109R | Missense Mutation (SNP) | VAF 136/268 reads (51%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- KREMEN2 | c.394G>C p.G132R | Missense Mutation (SNP) | VAF 101/323 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KRT16 | c.1014_1032del p.V339Lfs*9 | Frame Shift Del (DEL) | VAF 131/492 reads (27%) | called by mutect2, pindel, varscan2
- KRTAP11-1 | c.367C>T p.P123S | Missense Mutation (SNP) | VAF 144/386 reads (37%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.769); called by muse, mutect2, varscan2
- LCE4A | c.128_129insTAG p.S45dup | In Frame Ins (INS) | VAF 203/426 reads (48%) | called by mutect2, varscan2*
- LRRC40 | c.566T>C p.V189A | Missense Mutation (SNP) | VAF 39/126 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- LTBP4 | c.1243G>A p.D415N (on ENST00000308370 / NM_001042544.1; = p.D378N on NM_003573.2) | Missense Mutation (SNP) | VAF 145/307 reads (47%) | SIFT tolerated (0.1); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- LTN1 | c.899C>G p.S300* | Nonsense Mutation (SNP) | VAF 83/387 reads (21%) | called by muse, mutect2, varscan2
- MAGEB4 | c.718G>T p.E240* | Nonsense Mutation (SNP) | VAF 81/122 reads (66%) | called by muse, mutect2, varscan2
- MAN1A1 | c.711A>T p.K237N | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT tolerated (0.31); PolyPhen benign (0.185); called by muse, mutect2, varscan2
- MAP2K4 | c.164C>T p.S55F | Missense Mutation (SNP) | VAF 32/124 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAP2K7 | c.226G>T p.G76W | Missense Mutation (SNP) | VAF 39/108 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.319); called by muse, mutect2, varscan2
- MEF2C | c.1223A>C p.Y408S | Missense Mutation (SNP) | VAF 127/266 reads (48%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- MNT | c.15_19del p.L6Gfs*18 | Frame Shift Del (DEL) | VAF 52/368 reads (14%) | called by mutect2, pindel, varscan2
- MOSMO | c.245C>T p.T82I | Missense Mutation (SNP) | VAF 140/394 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.675); called by muse, mutect2, varscan2
- MPHOSPH10 | c.1823G>C p.G608A | Missense Mutation (SNP) | VAF 99/303 reads (33%) | SIFT tolerated (0.56); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- MS4A4E | c.340T>A p.W114R | Missense Mutation (SNP) | VAF 33/87 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- MTBP | c.2410A>G p.T804A | Missense Mutation (SNP) | VAF 105/431 reads (24%) | SIFT tolerated (0.46); PolyPhen benign (0); called by muse, mutect2, varscan2
- MTUS2 | c.186_187del p.T63Kfs*4 | Frame Shift Del (DEL) | VAF 81/273 reads (30%) | called by mutect2, pindel, varscan2
- MYBPC1 | c.823G>T p.E275* (on ENST00000550270 / NM_206820.2; = p.E300* on NM_002465.4) | Nonsense Mutation (SNP) | VAF 152/617 reads (25%) | called by muse, mutect2, varscan2
- MYCBP2 | c.5377G>T p.V1793L (on ENST00000357337; = p.V1831L on NM_015057.5) | Missense Mutation (SNP) | VAF 50/90 reads (56%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- MYO16 | c.4127C>T p.P1376L | Missense Mutation (SNP) | VAF 114/199 reads (57%) | SIFT tolerated (0.82); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- MYO7A | c.1270C>T p.Q424* | Nonsense Mutation (SNP) | VAF 126/264 reads (48%) | called by muse, mutect2, varscan2
- MYO7B | c.94A>C p.K32Q | Missense Mutation (SNP) | VAF 53/150 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- MYO9B | c.564del p.F189Lfs*12 | Frame Shift Del (DEL) | VAF 110/407 reads (27%) | called by mutect2, pindel, varscan2
- NAP1L3 | c.79A>T p.S27C | Missense Mutation (SNP) | VAF 92/116 reads (79%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NBEA | c.1068G>T p.M356I | Missense Mutation (SNP) | VAF 73/127 reads (57%) | SIFT tolerated (0.72); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- NCOR2 | c.3521C>A p.P1174Q | Missense Mutation (SNP) | VAF 130/280 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NISCH | c.805G>T p.E269* | Nonsense Mutation (SNP) | VAF 143/251 reads (57%) | called by muse, mutect2, varscan2
- NOB1 | c.1163G>T p.R388L | Missense Mutation (SNP) | VAF 131/417 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.66); called by muse, mutect2, varscan2
- NOS3 | c.3200G>A p.R1067H | Missense Mutation (SNP) | VAF 107/319 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.817); called by muse, mutect2, varscan2
- NOTCH1 | c.7061T>A p.L2354H | Missense Mutation (SNP) | VAF 111/194 reads (57%) | SIFT tolerated (0.49); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- NR1H4 | c.544del p.D182Ifs*13 (on ENST00000551379 / NM_001206993.2; = p.D172Ifs*13 on NM_005123.4) | Frame Shift Del (DEL) | VAF 121/301 reads (40%) | called by mutect2, pindel, varscan2
- NRF1 | c.229G>T p.V77L | Missense Mutation (SNP) | VAF 62/167 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- NRG3 | c.1831C>A p.L611M (on ENST00000404547 / NM_001370084.1; = p.L587M on NM_001010848.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 142/389 reads (37%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- NRXN2 | c.4263A>T p.L1421F | Missense Mutation (SNP) | VAF 129/563 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.655); called by muse, mutect2, varscan2
- NSD1 | c.5510-1G>C p.X1837_splice | Splice Site (SNP) | VAF 91/179 reads (51%) | called by muse, mutect2, varscan2
- OR10A6 | c.167A>G p.H56R | Missense Mutation (SNP) | VAF 65/144 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- OR2A12 | c.351G>T p.M117I | Missense Mutation (SNP) | VAF 34/85 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.902); called by muse, mutect2, varscan2
- OR4N2 | c.505T>C p.C169R | Missense Mutation (SNP) | VAF 155/918 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- OR52B6 | c.545T>A p.L182H | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- OR8K5 | c.777C>A p.Y259* | Nonsense Mutation (SNP) | VAF 50/153 reads (33%) | called by muse, mutect2, varscan2
- OTOGL | c.2982C>A p.D994E (on ENST00000547103; = p.D985E on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 54/103 reads (52%) | SIFT tolerated (0.39); PolyPhen benign (0.226); called by muse, mutect2, varscan2
- PALD1 | c.1729C>A p.L577M | Missense Mutation (SNP) | VAF 37/99 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- PALM2AKAP2 | c.106G>T p.G36C (on ENST00000259318 / NM_001136562.3; = p.G267C on NM_007203.5) | Missense Mutation (SNP) | VAF 46/89 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PARP4 | c.3227C>G p.P1076R | Missense Mutation (SNP) | VAF 24/228 reads (11%) | SIFT tolerated (0.69); PolyPhen benign (0.011); called by mutect2, varscan2
- PCDHB12 | c.1414A>T p.S472C | Missense Mutation (SNP) | VAF 318/590 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- PCDHGB3 | c.791T>C p.V264A | Missense Mutation (SNP) | VAF 90/188 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- PCNX3 | c.5306_5321del p.I1769Tfs*73 | Frame Shift Del (DEL) | VAF 343/816 reads (42%) | called by mutect2, pindel, varscan2
- PDZD2 | c.3010G>A p.V1004I | Missense Mutation (SNP) | VAF 66/285 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PGA5 | c.1153del p.A385Pfs*28 | Frame Shift Del (DEL) | VAF 104/400 reads (26%) | called by mutect2, pindel, varscan2
- PIWIL1 | c.388T>A p.Y130N | Missense Mutation (SNP) | VAF 99/391 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- PKDCC | c.1144C>A p.L382M | Missense Mutation (SNP) | VAF 159/323 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- PKHD1L1 | c.12305C>G p.P4102R | Missense Mutation (SNP) | VAF 61/141 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PLCH1 | c.1205G>A p.R402K (on ENST00000340059 / NM_001130960.2; = p.R414K on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 64/260 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- PLEKHH2 | c.3510T>G p.D1170E | Missense Mutation (SNP) | VAF 43/155 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- PLPP7 | c.170G>C p.R57T | Missense Mutation (SNP) | VAF 27/43 reads (63%) | SIFT tolerated (0.34); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- PNPLA7 | c.2776A>G p.I926V | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT tolerated (0.22); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- POLR3E | c.305T>C p.F102S | Missense Mutation (SNP) | VAF 101/322 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- POTED | c.174G>C p.R58S | Missense Mutation (SNP) | VAF 66/225 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.227); called by muse, mutect2, varscan2
- POTED | c.1513G>T p.E505* | Nonsense Mutation (SNP) | VAF 28/81 reads (35%) | called by muse, mutect2, varscan2
- PPFIA4 | c.3426G>C p.E1142D (on ENST00000447715; = p.E1143D on NM_001304331.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 52/120 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- PPIAL4C | c.343T>A p.C115S | Missense Mutation (SNP) | VAF 196/588 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.471); called by muse, mutect2, varscan2
- PPP1R1A | c.182A>G p.K61R | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.987); called by muse, varscan2
- PRAME | c.1108C>A p.Q370K | Missense Mutation (SNP) | VAF 63/178 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.17); called by muse, mutect2, varscan2
- PRDM14 | c.137T>C p.V46A | Missense Mutation (SNP) | VAF 110/382 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRDM16 | c.1621C>T p.H541Y | Missense Mutation (SNP) | VAF 48/112 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.469); called by muse, mutect2, varscan2
- PRG4 | c.2994G>T p.M998I | Missense Mutation (SNP) | VAF 81/288 reads (28%) | SIFT tolerated (0.47); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PRKG1 | c.902A>G p.K301R | Missense Mutation (SNP) | VAF 48/120 reads (40%) | SIFT tolerated (0.61); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PRL | c.28+1G>C p.X10_splice | Splice Site (SNP) | VAF 56/182 reads (31%) | called by muse, mutect2, varscan2
- PRPF4B | c.2691G>A p.M897I | Missense Mutation (SNP) | VAF 41/135 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- PRRC2C | c.3943A>G p.I1315V (on ENST00000367742; = p.I1313V on NM_015172.4) | Missense Mutation (SNP) | VAF 87/174 reads (50%) | SIFT tolerated (0.99); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRRT3 | c.2123A>C p.E708A | Missense Mutation (SNP) | VAF 90/162 reads (56%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.79); called by muse, mutect2, varscan2
- PRTG | c.38C>G p.P13R | Missense Mutation (SNP) | VAF 122/438 reads (28%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.131); called by muse, varscan2
- PRUNE2 | c.7978G>C p.V2660L | Missense Mutation (SNP) | VAF 77/149 reads (52%) | SIFT tolerated (0.46); PolyPhen benign (0); called by muse, mutect2, varscan2
- PTPN14 | c.2754G>C p.K918N | Missense Mutation (SNP) | VAF 170/347 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PTPRM | c.471G>T p.V157= | Splice Region (SNP) | VAF 60/115 reads (52%) | called by muse, mutect2, varscan2
- RAB11FIP5 | c.1345G>C p.E449Q | Missense Mutation (SNP) | VAF 181/578 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- REG1B | c.411T>A p.C137* | Nonsense Mutation (SNP) | VAF 94/289 reads (33%) | called by muse, mutect2, varscan2
- REG3A | c.64T>C p.S22P | Missense Mutation (SNP) | VAF 82/225 reads (36%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- REXO5 | c.1423T>A p.F475I | Missense Mutation (SNP) | VAF 30/121 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- RHOT2 | c.1102G>T p.V368L | Missense Mutation (SNP) | VAF 82/227 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- RIPOR3 | c.1330G>T p.E444* | Nonsense Mutation (SNP) | VAF 53/170 reads (31%) | called by muse, mutect2, varscan2
- RMDN1 | c.220G>C p.A74P | Missense Mutation (SNP) | VAF 48/139 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RNASE10 | c.433C>G p.L145V | Missense Mutation (SNP) | VAF 34/85 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- RNF111 | c.2586_2592dup p.S865Hfs*19 | Frame Shift Ins (INS) | VAF 31/165 reads (19%) | called by mutect2, varscan2
- RPS6KA6 | c.224T>A p.L75* | Nonsense Mutation (SNP) | VAF 35/56 reads (63%) | called by muse, mutect2, varscan2
- SACS | c.5663G>T p.G1888V | Missense Mutation (SNP) | VAF 55/176 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- SAFB2 | c.2107G>C p.E703Q | Missense Mutation (SNP) | VAF 136/446 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- SCAPER | c.2782A>G p.K928E | Missense Mutation (SNP) | VAF 77/402 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.437); called by muse, mutect2, varscan2
- SCN10A | c.1229A>G p.E410G | Missense Mutation (SNP) | VAF 166/328 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SEMA6C | c.404C>A p.T135K | Missense Mutation (SNP) | VAF 112/514 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SEPHS1 | c.322C>T p.L108F | Missense Mutation (SNP) | VAF 99/362 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); called by muse, mutect2, varscan2
- SETD2 | c.6758G>A p.S2253N | Missense Mutation (SNP) | VAF 53/92 reads (58%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SETD4 | c.279A>C p.L93F | Missense Mutation (SNP) | VAF 77/302 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- SETDB2 | c.1741G>T p.D581Y | Missense Mutation (SNP) | VAF 68/119 reads (57%) | SIFT deleterious (0.01); PolyPhen benign (0.342); called by muse, mutect2, varscan2
- SIN3B | c.3393G>A p.M1131I | Missense Mutation (SNP) | VAF 167/524 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- SLAMF7 | c.829C>A p.H277N | Missense Mutation (SNP) | VAF 130/309 reads (42%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC24A2 | c.122G>A p.G41D | Missense Mutation (SNP) | VAF 11/16 reads (69%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- SLC35E1 | c.221C>G p.P74R | Missense Mutation (SNP) | VAF 136/407 reads (33%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- SLC4A10 | c.542T>C p.L181P | Missense Mutation (SNP) | VAF 47/121 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC4A10 | c.2084G>T p.W695L (on ENST00000446997 / NM_001354461.2; = p.W665L on NM_022058.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 41/141 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- SLC7A1 | c.1665G>T p.K555N | Missense Mutation (SNP) | VAF 36/100 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SMG1 | c.9830_9838del p.D3277_E3279del | In Frame Del (DEL) | VAF 75/197 reads (38%) | called by mutect2, pindel, varscan2
- SMIM13 | c.117G>T p.K39N | Missense Mutation (SNP) | VAF 77/229 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SOCS5 | c.769A>T p.T257S | Missense Mutation (SNP) | VAF 64/150 reads (43%) | SIFT tolerated (0.7); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- SPATA6 | c.314C>A p.T105K | Missense Mutation (SNP) | VAF 64/174 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- SPOPL | c.879G>T p.L293F | Missense Mutation (SNP) | VAF 53/187 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SQSTM1 | c.920T>C p.L307P | Missense Mutation (SNP) | VAF 134/261 reads (51%) | SIFT tolerated (0.15); PolyPhen benign (0.172); called by muse, mutect2, varscan2
- SYT3 | c.1527G>C p.E509D | Missense Mutation (SNP) | VAF 84/234 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- TAS2R38 | c.830T>G p.I277R | Missense Mutation (SNP) | VAF 122/315 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- TBC1D12 | c.2162A>G p.Q721R | Missense Mutation (SNP) | VAF 42/159 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.773); called by muse, mutect2, varscan2
- TDRD15 | c.1136T>A p.L379* | Nonsense Mutation (SNP) | VAF 13/44 reads (30%) | called by muse, mutect2, varscan2
- TENT5D | c.513del p.F171Lfs*3 | Frame Shift Del (DEL) | VAF 43/80 reads (54%) | called by mutect2, pindel, varscan2
- TLE2 | c.1865G>T p.R622L | Missense Mutation (SNP) | VAF 128/362 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- TMEM132E | c.1751T>A p.L584Q (on ENST00000321639; = p.L674Q on NM_001304438.2) | Missense Mutation (SNP) | VAF 49/157 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.66); called by muse, mutect2, varscan2
- TMEM229A | c.533T>G p.L178R | Missense Mutation (SNP) | VAF 160/520 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- TMEM260 | c.925A>G p.I309V | Missense Mutation (SNP) | VAF 42/133 reads (32%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, mutect2, varscan2
- TOX | c.65G>T p.G22V | Missense Mutation (SNP) | VAF 164/390 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TPM1 | c.230dup p.A78Gfs*5 | Frame Shift Ins (INS) | VAF 159/569 reads (28%) | called by mutect2, pindel, varscan2
- TRIL | c.749A>T p.Q250L | Missense Mutation (SNP) | VAF 139/387 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- TRIM24 | c.377G>T p.R126L | Missense Mutation (SNP) | VAF 33/83 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- TSPAN19 | c.31A>C p.K11Q | Missense Mutation (SNP) | VAF 24/42 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); called by muse, mutect2, varscan2
- TTC26 | c.4-2A>T p.X2_splice | Splice Site (SNP) | VAF 29/70 reads (41%) | called by muse, mutect2
- TTC3 | c.187G>T p.E63* | Nonsense Mutation (SNP) | VAF 20/90 reads (22%) | called by muse, mutect2, varscan2
- TTN | c.86880del p.N28962Mfs*12 (on ENST00000591111; = p.N21538Mfs*12 on NM_003319.4) | Frame Shift Del (DEL) | VAF 53/99 reads (54%) | called by mutect2, pindel, varscan2
- TTN | c.28978C>A p.P9660T (on ENST00000591111; = p.P8733T on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/55 reads (40%) | PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- TUBGCP6 | c.3272G>A p.G1091E | Missense Mutation (SNP) | VAF 199/645 reads (31%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TXNDC2 | c.950C>A p.S317Y (on ENST00000306084 / NM_001098529.2; = p.S250Y on NM_032243.6) | Missense Mutation (SNP) | VAF 142/261 reads (54%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- TYW5 | c.29G>T p.R10L | Missense Mutation (SNP) | VAF 88/371 reads (24%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2, varscan2
- UFL1 | c.200G>A p.R67K | Missense Mutation (SNP) | VAF 52/106 reads (49%) | SIFT tolerated (0.52); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- UGT1A10 | c.595G>A p.D199N | Missense Mutation (SNP) | VAF 93/180 reads (52%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.732); called by muse, mutect2, varscan2
- UNC13C | c.2810C>G p.P937R | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- UNC13C | c.3434C>A p.A1145D | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.447); called by muse, mutect2, varscan2
- UNKL | c.853A>G p.I285V | Missense Mutation (SNP) | VAF 81/253 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.454); called by muse, mutect2, varscan2
- URI1 | c.191G>A p.R64K | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- VPS13A | c.6224A>T p.E2075V | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT tolerated (0.24); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- VSIG8 | c.551G>A p.S184N | Missense Mutation (SNP) | VAF 148/664 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- VSTM2B | c.793del p.D265Tfs*9 | Frame Shift Del (DEL) | VAF 106/230 reads (46%) | called by mutect2, pindel*, varscan2
- WDR93 | c.1413A>T p.K471N | Missense Mutation (SNP) | VAF 207/536 reads (39%) | SIFT tolerated (0.26); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- XKR4 | c.183C>A p.C61* | Nonsense Mutation (SNP) | VAF 16/40 reads (40%) | called by muse, mutect2, varscan2
- ZBED9 | c.118C>G p.L40V | Missense Mutation (SNP) | VAF 135/425 reads (32%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ZDHHC17 | c.1816T>A p.F606I | Missense Mutation (SNP) | VAF 75/322 reads (23%) | SIFT tolerated (0.33); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF100 | c.203A>G p.Y68C | Missense Mutation (SNP) | VAF 48/192 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF292 | c.2151G>A p.M717I | Missense Mutation (SNP) | VAF 49/139 reads (35%) | SIFT tolerated (0.31); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- ZNF33B | c.88G>T p.D30Y | Missense Mutation (SNP) | VAF 71/203 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF41 | c.112A>T p.K38* | Nonsense Mutation (SNP) | VAF 192/274 reads (70%) | called by muse, mutect2, varscan2
- ZNF521 | c.2495A>C p.H832P | Missense Mutation (SNP) | VAF 79/253 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZNF521 | c.2494C>A p.H832N | Missense Mutation (SNP) | VAF 77/253 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZNF528 | c.1175G>C p.R392P | Missense Mutation (SNP) | VAF 33/85 reads (39%) | SIFT tolerated (0.2); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- ZNF595 | c.832C>T p.H278Y | Missense Mutation (SNP) | VAF 105/324 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- ZNF611 | c.762A>T p.L254F | Missense Mutation (SNP) | VAF 49/124 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- ZNF676 | c.1725C>A p.S575R (on ENST00000650058; = p.S543R on NM_001001411.3) | Missense Mutation (SNP) | VAF 92/291 reads (32%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.741); called by muse, mutect2, varscan2
- ZNF778 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 118/340 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ZNF799 | c.1127A>T p.H376L | Missense Mutation (SNP) | VAF 110/356 reads (31%) | SIFT tolerated (0.64); PolyPhen possibly damaging (0.752); called by muse, mutect2, varscan2
- ZSCAN23 | c.964C>G p.H322D | Missense Mutation (SNP) | VAF 40/167 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.757); called by muse, mutect2, varscan2
- ZSCAN23 | c.963C>A p.F321L | Missense Mutation (SNP) | VAF 42/170 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.755); called by muse, mutect2, varscan2
- ZSCAN23 | c.541C>A p.P181T | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- AC018630.4 | c.9G>A p.R3= | Silent (SNP) | VAF 42/58 reads (72%) | called by muse, mutect2, varscan2
- ANO3 | c.100C>A p.R34= | Silent (SNP) | VAF 87/163 reads (53%) | catalogued as COSV99880783; called by muse, mutect2, varscan2
- APLNR | c.294G>T p.G98= | Silent (SNP) | VAF 158/474 reads (33%) | called by muse, mutect2, varscan2
- AQP4 | c.321C>A p.T107= | Silent (SNP) | VAF 208/668 reads (31%) | called by muse, mutect2, varscan2
- ARID5A | c.798G>A p.Q266= | Silent (SNP) | VAF 402/581 reads (69%) | catalogued as COSV62591553; called by muse, mutect2, varscan2
- BPIFB2 | c.480G>C p.L160= | Silent (SNP) | VAF 78/156 reads (50%) | called by muse, mutect2, varscan2
- BRCA1 | c.3966A>G p.K1322= | Silent (SNP) | VAF 62/151 reads (41%) | called by muse, mutect2, varscan2
- C17orf80 | c.777A>T p.S259= | Silent (SNP) | VAF 53/155 reads (34%) | called by muse, mutect2, varscan2
- C1orf56 | c.775C>A p.R259= | Silent (SNP) | VAF 170/347 reads (49%) | called by muse, mutect2, varscan2
- CBLN2 | c.27C>A p.L9= | Silent (SNP) | VAF 16/23 reads (70%) | catalogued as rs780466365; called by muse, mutect2, varscan2
- CD226 | c.642C>G p.V214= | Silent (SNP) | VAF 135/252 reads (54%) | catalogued as COSV54612425; called by muse, mutect2, varscan2
- CDH10 | c.1071C>A p.P357= | Silent (SNP) | VAF 39/229 reads (17%) | called by muse, mutect2, varscan2
- CDH2 | c.1101G>T p.T367= | Silent (SNP) | VAF 36/215 reads (17%) | catalogued as COSV52273152; called by muse, mutect2
- CHPT1 | c.240G>T p.V80= | Silent (SNP) | VAF 81/272 reads (30%) | called by muse, mutect2, varscan2
- CHST9 | c.48T>G p.S16= | Silent (SNP) | VAF 48/153 reads (31%) | called by muse, mutect2, varscan2
- CNTN3 | c.753C>A p.A251= | Silent (SNP) | VAF 67/111 reads (60%) | catalogued as COSV55166366; called by muse, mutect2, varscan2
- COIL | c.993G>T p.S331= | Silent (SNP) | VAF 51/144 reads (35%) | called by muse, mutect2, varscan2
- COL13A1 | c.756G>A p.P252= (on ENST00000398978 / NM_001130103.2; = p.P195= on NM_080798.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 39/105 reads (37%) | catalogued as rs538730570, COSV62568929; called by muse, mutect2, varscan2
- COL22A1 | c.4146C>G p.V1382= | Silent (SNP) | VAF 70/342 reads (20%) | called by muse, mutect2, varscan2
- COL4A3 | c.804C>G p.G268= | Silent (SNP) | VAF 150/307 reads (49%) | called by muse, mutect2, varscan2
- COL6A1 | c.2853G>T p.T951= | Silent (SNP) | VAF 58/161 reads (36%) | called by muse, mutect2, varscan2
- COL6A3 | c.4323C>T p.I1441= | Silent (SNP) | VAF 82/154 reads (53%) | catalogued as rs747160916; ClinVar: likely benign; called by muse, mutect2, varscan2
- COPA | c.3600C>A p.I1200= | Silent (SNP) | VAF 96/165 reads (58%) | catalogued as COSV54100817, COSV54110269; called by muse, mutect2
- CUX2 | c.2502C>A p.P834= | Silent (SNP) | VAF 190/366 reads (52%) | catalogued as COSV99918794; called by muse, varscan2
- DCTN2 | c.1185G>A p.R395= (on ENST00000548249 / NM_001261413.2; = p.R400= on NM_006400.4) | Silent (SNP) | VAF 135/278 reads (49%) | called by muse, mutect2, varscan2
- DIRAS1 | c.511C>A p.R171= | Silent (SNP) | VAF 40/165 reads (24%) | called by muse, mutect2, varscan2
- DMD | c.8700C>A p.V2900= | Silent (SNP) | VAF 135/193 reads (70%) | catalogued as COSV100626183; called by muse, mutect2, varscan2
- DNAH8 | c.12450T>A p.T4150= | Silent (SNP) | VAF 41/125 reads (33%) | called by muse, mutect2, varscan2
- EGFL8 | c.117C>T p.S39= | Silent (SNP) | VAF 125/317 reads (39%) | catalogued as COSV100247068, COSV61247009; called by muse, mutect2, varscan2
- ELFN2 | c.1533G>T p.G511= | Silent (SNP) | VAF 100/288 reads (35%) | called by muse, mutect2, varscan2
- FAM237A | c.207T>C p.V69= | Silent (SNP) | VAF 81/112 reads (72%) | called by muse, mutect2, varscan2
- FANCA | c.3129C>G p.S1043= | Silent (SNP) | VAF 160/557 reads (29%) | called by muse, mutect2, varscan2
- FBN1 | c.7608G>T p.G2536= | Silent (SNP) | VAF 163/497 reads (33%) | called by muse, mutect2, varscan2
- FBN2 | c.2055C>T p.P685= | Silent (SNP) | VAF 149/298 reads (50%) | called by muse, mutect2, varscan2
- FGFR1 | c.471C>T p.S157= (on ENST00000447712 / NM_023110.3; = p.S155= on NM_015850.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 84/222 reads (38%) | catalogued as rs376497452; called by muse, mutect2, varscan2
- FSHR | c.135G>T p.P45= | Silent (SNP) | VAF 150/488 reads (31%) | catalogued as COSV58623836; called by muse, mutect2, varscan2
- FZD10 | c.852C>A p.G284= | Silent (SNP) | VAF 146/297 reads (49%) | called by muse, mutect2, varscan2
- GPR17 | c.351C>A p.V117= | Silent (SNP) | VAF 195/606 reads (32%) | called by muse, mutect2, varscan2
- GRM7 | c.234G>A p.R78= | Silent (SNP) | VAF 58/103 reads (56%) | catalogued as rs758534483; called by muse, mutect2, varscan2
- GRM8 | c.2376C>T p.I792= | Silent (SNP) | VAF 27/94 reads (29%) | catalogued as rs866776649, COSV58818821; called by muse, mutect2, varscan2
- H2BC5 | c.105G>A p.K35= | Silent (SNP) | VAF 125/383 reads (33%) | catalogued as rs1382738592; called by muse, mutect2, varscan2
- HBZ | c.39C>A p.S13= | Silent (SNP) | VAF 145/407 reads (36%) | called by muse, mutect2
- HCN1 | c.45C>T p.D15= | Silent (SNP) | VAF 61/172 reads (35%) | catalogued as rs760319799, COSV100298074; called by muse, mutect2, varscan2
- HOXD11 | c.498C>T p.S166= | Silent (SNP) | VAF 122/400 reads (31%) | called by muse, mutect2, varscan2
- HROB | c.906G>A p.Q302= | Silent (SNP) | VAF 107/343 reads (31%) | called by muse, mutect2, varscan2
- HSPG2 | c.7317C>A p.V2439= | Silent (SNP) | VAF 158/449 reads (35%) | catalogued as COSV65976772; called by muse, mutect2, varscan2
- HUNK | c.642G>T p.L214= | Silent (SNP) | VAF 54/173 reads (31%) | called by muse, mutect2, varscan2
- IGKV1-16 | c.81C>G p.T27= | Silent (SNP) | VAF 156/524 reads (30%) | called by muse, varscan2
- IGLL1 | c.306C>A p.T102= | Silent (SNP) | VAF 196/577 reads (34%) | called by muse, mutect2, varscan2
- IMPG1 | c.228G>T p.T76= | Silent (SNP) | VAF 121/381 reads (32%) | catalogued as rs372049150, COSV100886392; called by muse, mutect2, varscan2
- IQUB | c.12A>G p.Q4= | Silent (SNP) | VAF 8/14 reads (57%) | catalogued as rs755862929, COSV61237825; called by muse, mutect2, varscan2
- ITGB2 | c.2250G>T p.L750= (on ENST00000302347; = p.L726= on NM_000211.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 195/648 reads (30%) | called by muse, mutect2, varscan2
- JAKMIP1 | c.1410G>T p.T470= | Silent (SNP) | VAF 114/348 reads (33%) | catalogued as COSV51527699; called by muse, mutect2, varscan2
- JAZF1 | c.256C>T p.L86= | Silent (SNP) | VAF 62/196 reads (32%) | called by muse, mutect2, varscan2
- KCNT2 | c.3273C>A p.T1091= | Silent (SNP) | VAF 143/261 reads (55%) | catalogued as COSV54068154; called by muse, mutect2, varscan2
- KIAA0586 | c.2100T>A p.V700= (on ENST00000619416 / NM_001244190.2; = p.V639= on NM_014749.5) | Silent (SNP) | VAF 47/123 reads (38%) | catalogued as rs78009437; called by muse, mutect2, varscan2
- KRT5 | c.1062G>C p.R354= | Silent (SNP) | VAF 375/760 reads (49%) | called by muse, mutect2, varscan2
- LCT | c.2409T>C p.D803= | Silent (SNP) | VAF 70/185 reads (38%) | called by muse, mutect2, varscan2
- LIF | c.309G>T p.V103= | Silent (SNP) | VAF 180/513 reads (35%) | catalogued as rs745457739; called by mutect2, varscan2
- LMLN2 | c.490T>C p.L164= | Silent (SNP) | VAF 83/226 reads (37%) | called by muse, mutect2, varscan2
- MAGEB4 | c.717G>T p.G239= | Silent (SNP) | VAF 80/123 reads (65%) | called by muse, mutect2, varscan2
- MANBA | c.1434G>A p.V478= (on ENST00000642252; = p.V432= on NM_005908.4) | Silent (SNP) | VAF 262/394 reads (66%) | called by muse, mutect2, varscan2
- MAS1 | c.369G>T p.L123= | Silent (SNP) | VAF 154/526 reads (29%) | called by muse, mutect2, varscan2
- MAS1L | c.600G>A p.L200= | Silent (SNP) | VAF 65/155 reads (42%) | catalogued as rs546803745; called by muse, mutect2, varscan2
- MATN2 | c.2091C>T p.L697= | Silent (SNP) | VAF 111/179 reads (62%) | catalogued as COSV99646136; called by muse, mutect2, varscan2
- MITF | c.474A>G p.P158= (on ENST00000448226 / NM_006722.3; = p.P52= on NM_000248.4) | Silent (SNP) | VAF 151/274 reads (55%) | called by muse, mutect2, varscan2
- MMS19 | c.666C>T p.F222= | Silent (SNP) | VAF 84/229 reads (37%) | catalogued as COSV59136715; called by muse, mutect2, varscan2
- MNAT1 | c.909G>A p.G303= | Silent (SNP) | VAF 42/122 reads (34%) | called by muse, mutect2, varscan2
- MNT | c.319T>C p.L107= | Silent (SNP) | VAF 8/24 reads (33%) | called by muse, varscan2
- MPHOSPH10 | c.1201C>T p.L401= | Silent (SNP) | VAF 128/417 reads (31%) | catalogued as rs1180314254; called by muse, mutect2, varscan2
- MUC17 | c.1656T>C p.S552= | Silent (SNP) | VAF 130/372 reads (35%) | called by muse, varscan2
- MYO5C | c.1644C>T p.I548= | Silent (SNP) | VAF 51/139 reads (37%) | called by muse, mutect2, varscan2
- MYOM2 | c.2280C>T p.V760= | Silent (SNP) | VAF 72/140 reads (51%) | called by muse, varscan2
- NBEA | c.2541G>T p.V847= | Silent (SNP) | VAF 32/189 reads (17%) | called by muse, mutect2, varscan2
- NBEA | c.5730A>T p.L1910= | Silent (SNP) | VAF 161/265 reads (61%) | called by muse, mutect2, varscan2
- NDST2 | c.498G>C p.V166= | Silent (SNP) | VAF 68/216 reads (31%) | catalogued as COSV100013849; called by muse, mutect2, varscan2
- NEB | c.19758C>G p.L6586= | Silent (SNP) | VAF 41/89 reads (46%) | called by muse, mutect2, varscan2
- NFE2L3 | c.141G>A p.L47= | Silent (SNP) | VAF 82/258 reads (32%) | called by muse, mutect2, varscan2
- NIBAN3 | c.603G>A p.R201= | Silent (SNP) | VAF 109/362 reads (30%) | catalogued as COSV99962695; called by muse, mutect2, varscan2
- NOB1 | c.1164G>T p.R388= | Silent (SNP) | VAF 129/406 reads (32%) | called by muse, mutect2, varscan2
- NOVA1 | c.723A>T p.I241= | Silent (SNP) | VAF 66/209 reads (32%) | called by muse, mutect2, varscan2
- NPDC1 | c.663C>T p.Y221= | Silent (SNP) | VAF 140/294 reads (48%) | catalogued as rs139019177; called by muse, mutect2, varscan2
- OGFOD3 | c.957G>T p.P319= | Silent (SNP) | VAF 58/161 reads (36%) | called by muse, varscan2
- OR10C1 | c.234G>C p.T78= (on ENST00000622521; = p.T76= on NM_013941.3) | Silent (SNP) | VAF 70/208 reads (34%) | catalogued as rs943958508; called by muse, mutect2
- OR4K1 | c.237C>A p.P79= | Silent (SNP) | VAF 72/509 reads (14%) | catalogued as rs1284913226; called by muse, mutect2, varscan2
- OR5L1 | c.900T>A p.A300= | Silent (SNP) | VAF 40/93 reads (43%) | called by muse, mutect2, varscan2
- OR8D4 | c.327T>C p.I109= | Silent (SNP) | VAF 84/251 reads (33%) | called by muse, mutect2, varscan2
- PCDH9 | c.1555C>A p.R519= | Silent (SNP) | VAF 65/141 reads (46%) | catalogued as COSV60553431; called by muse, mutect2, varscan2
- PHACTR3 | c.1644A>C p.A548= | Silent (SNP) | VAF 41/134 reads (31%) | called by muse, mutect2, varscan2
- PHKG1 | c.183G>T p.P61= | Silent (SNP) | VAF 132/409 reads (32%) | catalogued as rs56278042, COSV52082082; called by muse, mutect2, varscan2
- PIK3CG | c.750C>T p.T250= | Silent (SNP) | VAF 82/227 reads (36%) | called by muse, mutect2, varscan2
- PLIN1 | c.870C>G p.A290= | Silent (SNP) | VAF 168/764 reads (22%) | catalogued as rs775295801; called by muse, mutect2, varscan2
- PMFBP1 | c.2631G>T p.V877= (on ENST00000537465; = p.V872= on NM_031293.3) | Silent (SNP) | VAF 32/102 reads (31%) | called by muse, mutect2, varscan2
- POLR1A | c.1554G>T p.V518= | Silent (SNP) | VAF 440/661 reads (67%) | called by muse, mutect2, varscan2
- POMT1 | c.1647G>T p.L549= | Silent (SNP) | VAF 180/350 reads (51%) | called by muse, mutect2, varscan2
- POU3F4 | c.744G>T p.L248= | Silent (SNP) | VAF 80/118 reads (68%) | called by muse, mutect2, varscan2
- PRAME | c.1107C>A p.L369= | Silent (SNP) | VAF 67/183 reads (37%) | called by muse, mutect2, varscan2
- PRKAR2B | c.657G>C p.G219= | Silent (SNP) | VAF 59/219 reads (27%) | called by muse, mutect2, varscan2
- PSME4 | c.1473G>T p.G491= | Silent (SNP) | VAF 43/112 reads (38%) | catalogued as rs941942716; called by muse, mutect2, varscan2
- PTN | c.211C>A p.R71= | Silent (SNP) | VAF 74/224 reads (33%) | catalogued as COSV100780986, COSV61968829; called by muse, mutect2, varscan2
- PTPRD | c.5196C>A p.L1732= | Silent (SNP) | VAF 24/83 reads (29%) | catalogued as rs373802637; called by muse, mutect2, varscan2
- RAB3D | c.354G>C p.T118= | Silent (SNP) | VAF 64/202 reads (32%) | catalogued as COSV99708955; called by muse, mutect2, varscan2
- RASSF5 | c.424C>A p.R142= | Silent (SNP) | VAF 26/90 reads (29%) | called by muse, mutect2, varscan2
- RBP3 | c.2361C>A p.G787= | Silent (SNP) | VAF 172/427 reads (40%) | catalogued as rs782380869; called by muse, mutect2, varscan2
- RIMS1 | c.1590G>A p.V530= | Silent (SNP) | VAF 143/379 reads (38%) | catalogued as rs568368656; called by muse, mutect2, varscan2
- ROBO3 | c.4059C>T p.S1353= | Silent (SNP) | VAF 117/321 reads (36%) | called by muse, mutect2, varscan2
- RXYLT1 | c.63C>T p.L21= | Silent (SNP) | VAF 235/927 reads (25%) | catalogued as rs752603218; called by muse, mutect2, varscan2
- SCAF1 | c.1407G>T p.A469= | Silent (SNP) | VAF 11/26 reads (42%) | catalogued as rs1157925555; called by muse, mutect2, varscan2
- SEMA4A | c.1476G>T p.V492= | Silent (SNP) | VAF 89/404 reads (22%) | called by muse, mutect2, varscan2
- SEMA5A | c.2817G>C p.P939= | Silent (SNP) | VAF 88/516 reads (17%) | called by muse, mutect2, varscan2
- SETD1A | c.3609G>A p.V1203= | Silent (SNP) | VAF 107/278 reads (38%) | called by muse, mutect2, varscan2
- SLC35E1 | c.304C>T p.L102= | Silent (SNP) | VAF 133/415 reads (32%) | called by muse, mutect2, varscan2
- SNED1 | c.2142G>A p.T714= | Silent (SNP) | VAF 126/263 reads (48%) | catalogued as rs776073165; called by muse, mutect2, varscan2
- SPACA4 | c.48C>A p.G16= | Silent (SNP) | VAF 50/173 reads (29%) | called by muse, mutect2, varscan2
- SPAM1 | c.141G>T p.V47= | Silent (SNP) | VAF 37/155 reads (24%) | catalogued as COSV56149170; called by muse, mutect2, varscan2
- STAB2 | c.3291G>A p.V1097= | Silent (SNP) | VAF 13/190 reads (7%) | catalogued as rs1373725175; called by muse, mutect2
- STYXL2 | c.684C>T p.G228= | Silent (SNP) | VAF 76/123 reads (62%) | catalogued as COSV54809179; called by muse, varscan2
- TAS2R46 | c.333C>T p.A111= | Silent (SNP) | VAF 84/184 reads (46%) | catalogued as COSV101113982; called by muse, varscan2
- TDG | c.348A>G p.E116= | Silent (SNP) | VAF 104/531 reads (20%) | called by muse, mutect2, varscan2
- TDRD15 | c.3753G>T p.V1251= | Silent (SNP) | VAF 31/75 reads (41%) | catalogued as rs944082787; called by muse, mutect2, varscan2
- TGIF2LX | c.564G>A p.Q188= | Silent (SNP) | VAF 254/376 reads (68%) | called by muse, mutect2, varscan2
- THSD7A | c.420A>G p.L140= | Silent (SNP) | VAF 105/361 reads (29%) | called by muse, mutect2, varscan2
- TMEM179 | c.492C>G p.S164= | Silent (SNP) | VAF 94/266 reads (35%) | called by muse, mutect2, varscan2
- TMEM74 | c.708C>T p.L236= | Silent (SNP) | VAF 63/176 reads (36%) | called by muse, mutect2, varscan2
- TNFAIP3 | c.783G>A p.V261= | Silent (SNP) | VAF 39/123 reads (32%) | called by muse, mutect2, varscan2
- TNR | c.1278C>A p.I426= | Silent (SNP) | VAF 170/367 reads (46%) | called by muse, mutect2, varscan2
- TPH2 | c.822G>T p.T274= | Silent (SNP) | VAF 182/809 reads (22%) | catalogued as COSV100422148; called by muse, mutect2, varscan2
- TRAV13-1 | c.297C>T p.T99= | Silent (SNP) | VAF 34/91 reads (37%) | called by muse, mutect2, varscan2
- TRAV39 | c.135C>T p.T45= | Silent (SNP) | VAF 114/328 reads (35%) | called by muse, mutect2, varscan2
- TRIL | c.1008G>T p.A336= | Silent (SNP) | VAF 62/184 reads (34%) | called by muse, mutect2, varscan2
- TSPAN8 | c.627T>C p.V209= | Silent (SNP) | VAF 48/145 reads (33%) | called by muse, mutect2, varscan2
- TTLL2 | c.522G>T p.L174= | Silent (SNP) | VAF 84/216 reads (39%) | called by muse, mutect2, varscan2
- TTN | c.88419T>A p.P29473= (on ENST00000591111; = p.P22049= on NM_003319.4) | Silent (SNP) | VAF 97/256 reads (38%) | catalogued as COSV59918755; called by muse, mutect2, varscan2
- TTN | c.1449C>T p.A483= | Silent (SNP) | VAF 79/269 reads (29%) | catalogued as rs141617218; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- UNC13A | c.1800C>T p.N600= | Silent (SNP) | VAF 56/184 reads (30%) | catalogued as rs1172433080; called by muse, mutect2, varscan2
- XDH | c.3525C>T p.L1175= | Silent (SNP) | VAF 183/836 reads (22%) | called by muse, mutect2, varscan2
- ZNF257 | c.600C>G p.S200= | Silent (SNP) | VAF 26/87 reads (30%) | called by muse, mutect2, varscan2
- ZNF280A | c.1447C>T p.L483= | Silent (SNP) | VAF 32/140 reads (23%) | called by muse, mutect2, varscan2
- ZNF280B | c.744T>C p.P248= | Silent (SNP) | VAF 63/177 reads (36%) | called by muse, mutect2, varscan2
- ZNF304 | c.780C>T p.F260= | Silent (SNP) | VAF 60/184 reads (33%) | called by muse, mutect2, varscan2
- ZNF366 | c.2127G>T p.R709= | Silent (SNP) | VAF 119/263 reads (45%) | called by muse, mutect2, varscan2
- ZNF585B | c.99T>A p.A33= | Silent (SNP) | VAF 100/174 reads (57%) | called by muse, mutect2, varscan2
- ZNF598 | c.1119C>G p.P373= | Silent (SNP) | VAF 159/452 reads (35%) | catalogued as rs1438242316; called by muse, mutect2, varscan2
- ZNF624 | c.732G>T p.G244= | Silent (SNP) | VAF 90/234 reads (38%) | called by muse, mutect2, varscan2
- ZNF766 | c.1002A>G p.K334= | Silent (SNP) | VAF 31/108 reads (29%) | called by muse, mutect2, varscan2
- AC055876.1 | n.556A>T | RNA (SNP) | VAF 14/32 reads (44%) | called by muse, mutect2, varscan2
- AC092718.9 | chr16:81154330 G>C | 3'Flank (SNP) | VAF 81/216 reads (38%) | catalogued as rs1483019574; called by muse, mutect2, varscan2
- AC099552.1 | n.309C>T | RNA (SNP) | VAF 58/172 reads (34%) | called by muse, mutect2, varscan2
- ACKR1 | c.-81G>A | 5'UTR (SNP) | VAF 208/403 reads (52%) | called by muse, mutect2, varscan2
- ADAM22 | c.86-137A>T | Intron (SNP) | VAF 13/43 reads (30%) | called by muse, mutect2, varscan2
- ADPRS | c.-5C>A | 5'UTR (SNP) | VAF 152/486 reads (31%) | called by muse, mutect2, varscan2
- AFF3 | c.54-2570C>T | Intron (SNP) | VAF 60/201 reads (30%) | called by muse, mutect2, varscan2
- AGAP7P | n.741C>A | RNA (SNP) | VAF 58/730 reads (8%) | called by muse, mutect2
- ALDH3A1 | c.*129G>T | 3'UTR (SNP) | VAF 44/134 reads (33%) | called by muse, mutect2, varscan2
- ALOXE3 | c.1786-18G>A | Intron (SNP) | VAF 140/411 reads (34%) | called by muse, mutect2, varscan2
- ANKIB1 | c.-148G>A | 5'UTR (SNP) | VAF 206/620 reads (33%) | catalogued as rs1563339983; called by muse, mutect2, varscan2
- AP003062.1 | n.946C>A | RNA (SNP) | VAF 176/611 reads (29%) | called by muse, mutect2, varscan2
- ASB5 | c.197-16146C>A | Intron (SNP) | VAF 46/97 reads (47%) | called by muse, mutect2, varscan2
- ATP10B | c.470+1063T>A | Intron (SNP) | VAF 60/125 reads (48%) | called by muse, mutect2, varscan2
- AVIL | c.1333-18G>T | Intron (SNP) | VAF 174/701 reads (25%) | called by muse, mutect2, varscan2
- BCHE | c.1685-5200G>T | Intron (SNP) | VAF 30/198 reads (15%) | called by muse, mutect2, varscan2
- BTK | c.1566+51T>C | Intron (SNP) | VAF 139/198 reads (70%) | catalogued as rs782342481; called by muse, mutect2, varscan2
- BTN1A1P1 | chr6:26476173 G>C | 5'Flank (SNP) | VAF 62/219 reads (28%) | called by muse, mutect2, varscan2
- BVES-AS1 | n.682C>A | RNA (SNP) | VAF 31/127 reads (24%) | called by muse, mutect2, varscan2
- C10orf90 | c.-66A>T | 5'UTR (SNP) | VAF 101/333 reads (30%) | called by muse, mutect2, varscan2
- CARD11 | c.*1G>C | 3'UTR (SNP) | VAF 43/146 reads (29%) | called by muse, mutect2, varscan2
- CD36 | c.819-29G>A | Intron (SNP) | VAF 28/96 reads (29%) | called by muse, mutect2, varscan2
- CELF4 | c.658-111C>T | Intron (SNP) | VAF 63/176 reads (36%) | catalogued as rs754599511; called by muse, mutect2, varscan2
- CLRN1 | c.*138A>G | 3'UTR (SNP) | VAF 166/232 reads (72%) | called by muse, varscan2
- CTDSP2 | c.-14C>A | 5'UTR (SNP) | VAF 93/373 reads (25%) | called by muse, mutect2, varscan2
- CXCR5 | c.51+2308T>C | Intron (SNP) | VAF 66/242 reads (27%) | called by muse, mutect2, varscan2
- DAO | chr12:108876895 T>C | 5'Flank (SNP) | VAF 122/273 reads (45%) | called by muse, mutect2, varscan2
- DCAF17 | c.*1434A>G | 3'UTR (SNP) | VAF 145/407 reads (36%) | called by muse, mutect2, varscan2
- DCHS2 | n.7747C>A | RNA (SNP) | VAF 98/196 reads (50%) | catalogued as COSV61769128; called by muse, mutect2, varscan2
- DSC1 | c.2488-87del | Intron (DEL) | VAF 18/61 reads (30%) | called by mutect2, pindel, varscan2
- ELK1 | chrX:47650572 C>G | 5'Flank (SNP) | VAF 19/31 reads (61%) | called by muse, mutect2, varscan2
- EML2 | chr19:45642084 G>A | 5'Flank (SNP) | VAF 9/21 reads (43%) | called by muse, mutect2, varscan2
- EREG | c.*4G>T | 3'UTR (SNP) | VAF 48/145 reads (33%) | called by muse, mutect2, varscan2
- ERICH3 | c.603+1595G>T | Intron (SNP) | VAF 46/118 reads (39%) | called by muse, mutect2, varscan2
- EYS | c.8072-2980T>C | Intron (SNP) | VAF 11/29 reads (38%) | catalogued as rs1049463364; called by muse, mutect2, varscan2
- FAM13C | c.1634+18G>C | Intron (SNP) | VAF 47/146 reads (32%) | catalogued as COSV53257404; called by muse, mutect2, varscan2
- FAM74A3 | n.369C>A | RNA (SNP) | VAF 162/362 reads (45%) | called by muse, mutect2, varscan2
- GALK1 | c.476-47_476-39del | Intron (DEL) | VAF 41/127 reads (32%) | called by mutect2, pindel, varscan2
- GDAP1L1 | c.*339T>A | 3'UTR (SNP) | VAF 122/332 reads (37%) | called by muse, varscan2
- GP2 | chr16:20327691 T>C | 5'Flank (SNP) | VAF 125/390 reads (32%) | called by muse, mutect2, varscan2
- HMGN1 | chr21:39349511 G>T | 5'Flank (SNP) | VAF 37/128 reads (29%) | called by muse, mutect2, varscan2
- INO80E | c.-43G>T | 5'UTR (SNP) | VAF 76/205 reads (37%) | called by muse, mutect2, varscan2
- LINC00587 | n.138A>G | RNA (SNP) | VAF 46/100 reads (46%) | called by muse, mutect2, varscan2
- LINC00868 | n.743T>A | RNA (SNP) | VAF 134/392 reads (34%) | catalogued as rs1043931814; called by muse, mutect2
- MAD1L1 | c.1074-10380G>T | Intron (SNP) | VAF 118/362 reads (33%) | called by muse, mutect2, varscan2
- MAGEA5 | n.272A>G | RNA (SNP) | VAF 135/191 reads (71%) | called by muse, mutect2, varscan2
- MAP2K7 | c.124+401C>T | Intron (SNP) | VAF 64/208 reads (31%) | catalogued as rs1417194571; called by muse, mutect2, varscan2
- MIR205 | chr1:209430498 ins GAGT | 5'Flank (INS) | VAF 98/226 reads (43%) | called by mutect2, varscan2
- MIR30A | n.67G>A | RNA (SNP) | VAF 82/274 reads (30%) | called by muse, mutect2, varscan2
- MIR588 | n.15T>A | RNA (SNP) | VAF 40/127 reads (31%) | called by muse, mutect2, varscan2
- MLXIPL | c.*6G>T | 3'UTR (SNP) | VAF 160/491 reads (33%) | catalogued as COSV100515591; called by muse, varscan2
- NBPF22P | n.1370C>T | RNA (SNP) | VAF 98/166 reads (59%) | called by muse, mutect2, varscan2
- NR1I2 | c.-23+529T>A | Intron (SNP) | VAF 159/492 reads (32%) | catalogued as COSV61977389; called by muse, mutect2, varscan2
- NRXN1 | c.820+64A>T | Intron (SNP) | VAF 102/311 reads (33%) | called by muse, mutect2, varscan2
- OR10D1P | n.602T>C | RNA (SNP) | VAF 13/36 reads (36%) | called by muse, mutect2, varscan2
- OR4F13P | n.1222_1225delinsT | RNA (DEL) | VAF 26/224 reads (12%) | called by pindel, varscan2*
- OR9G4 | chr11:56741038 C>G | 3'Flank (SNP) | VAF 23/93 reads (25%) | called by muse, mutect2
- OTOF | c.*231C>A | 3'UTR (SNP) | VAF 30/46 reads (65%) | catalogued as COSV99717659; called by muse, mutect2, varscan2
- OTOGL | c.6268-237G>A | Intron (SNP) | VAF 42/175 reads (24%) | called by muse, mutect2, varscan2
- PDGFRA | c.-13+10666G>T | Intron (SNP) | VAF 61/146 reads (42%) | called by muse, varscan2
- PIP5K1B | c.1502+22401T>C | Intron (SNP) | VAF 61/121 reads (50%) | called by muse, mutect2, varscan2
- PLXNC1 | c.2882-254T>A | Intron (SNP) | VAF 114/222 reads (51%) | called by muse, mutect2, varscan2
- POR | c.237+54A>G | Intron (SNP) | VAF 82/289 reads (28%) | called by muse, mutect2, varscan2
- RBFOX1 | c.351+152582G>T | Intron (SNP) | VAF 89/246 reads (36%) | catalogued as rs899106482; called by muse, mutect2, varscan2
- REEP2 | c.-41G>A | 5'UTR (SNP) | VAF 60/89 reads (67%) | called by muse, mutect2, varscan2
- RFK | chr9:76399048 G>C | 5'Flank (SNP) | VAF 240/461 reads (52%) | catalogued as rs775381541; called by muse, mutect2, varscan2
- RN7SL484P | chr15:99790397 C>G | 5'Flank (SNP) | VAF 45/221 reads (20%) | called by muse, mutect2, varscan2
- RNU7-174P | chr8:80559264 A>T | 5'Flank (SNP) | VAF 210/624 reads (34%) | called by muse, mutect2, varscan2
- SCPEP1 | c.-13T>A | 5'UTR (SNP) | VAF 106/341 reads (31%) | called by muse, mutect2, varscan2
- SSH1 | c.*26G>T | 3'UTR (SNP) | VAF 172/360 reads (48%) | catalogued as COSV58456074; called by muse, mutect2, varscan2
- SSPOP | n.6728G>T | RNA (SNP) | VAF 159/515 reads (31%) | called by muse, mutect2, varscan2
- SSPOP | n.8193G>A | RNA (SNP) | VAF 53/183 reads (29%) | called by muse, mutect2, varscan2
- STEAP3 | c.*125T>G | 3'UTR (SNP) | VAF 75/193 reads (39%) | called by muse, mutect2, varscan2
- STIM2 | c.1764-980A>G | Intron (SNP) | VAF 105/338 reads (31%) | called by muse, mutect2, varscan2
- TAC4 | c.123+722C>T | Intron (SNP) | VAF 121/403 reads (30%) | called by muse, mutect2, varscan2
- TBC1D3P1 | n.358_379del | RNA (DEL) | VAF 86/556 reads (15%) | called by mutect2, varscan2
- TBX2 | c.1051+174G>C | Intron (SNP) | VAF 158/475 reads (33%) | catalogued as rs1445534080; called by muse, mutect2, varscan2
- TMEM37 | chr2:119430399 G>T | 5'Flank (SNP) | VAF 69/277 reads (25%) | catalogued as rs1161944140; called by muse, mutect2, varscan2
- TMIGD2 | c.-31G>C | 5'UTR (SNP) | VAF 37/108 reads (34%) | called by muse, mutect2, varscan2
- TPM1 | c.563+211A>C | Intron (SNP) | VAF 125/384 reads (33%) | catalogued as rs774918887; called by muse, mutect2, varscan2
- TRIM51BP | n.1132T>C | RNA (SNP) | VAF 23/88 reads (26%) | called by mutect2, varscan2
- TSSC2 | n.288-5417A>T | Intron (SNP) | VAF 114/221 reads (52%) | called by muse, mutect2, varscan2
- UBA6 | chr4:67701320 C>G | 5'Flank (SNP) | VAF 70/147 reads (48%) | called by muse, mutect2, varscan2
- UFD1 | c.849+89del | Intron (DEL) | VAF 27/78 reads (35%) | called by mutect2, pindel, varscan2
- UNC79 | c.3754+1536G>T | Intron (SNP) | VAF 49/174 reads (28%) | called by muse, mutect2, varscan2
- UTRN | c.7479+6214A>T | Intron (SNP) | VAF 26/91 reads (29%) | called by muse, mutect2, varscan2
- ZNF140 | c.-9C>A | 5'UTR (SNP) | VAF 29/183 reads (16%) | catalogued as COSV60579795; called by muse, mutect2, varscan2
- ZNF419 | c.199+37G>C | Intron (SNP) | VAF 133/372 reads (36%) | called by muse, mutect2, varscan2
- ZNF419 | c.199+38G>T | Intron (SNP) | VAF 129/354 reads (36%) | called by mutect2, varscan2
- ZNF721 | chr4:437505 C>A | 3'Flank (SNP) | VAF 45/166 reads (27%) | called by muse, mutect2, varscan2
